Somatic mutation profile of tumor specimen ALCH-B1OT-TTP1-A (aliquot ALCH-B1OT-TTP1-A-1-0-D-A76C-36) from ALCHEMIST case ALCH-B1OT, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 55.1 years (20,139 days).
Specimen ALCH-B1OT-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 65396b7e-81c1-40e5-bd94-d31085c8732b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B1OT-NB1-A (Blood Derived Normal), aliquot ALCH-B1OT-NB1-A-1-0-D-A76C-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8f37794f-3498-4a59-9932-0c52a675b1fa

The open-access MAF lists 2,246 somatic variants for this specimen: 1,537 protein-altering or splice-affecting, 431 silent, 278 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,322, Silent 431, Intron 121, Nonsense Mutation 101, RNA 46, 3'UTR 42, Splice Site 38, 5'UTR 37, Frame Shift Del 35, Splice Region 27, 5'Flank 21, Frame Shift Ins 12.

Variants (750 of 2,246; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- B4GALT7 | c.421C>T p.R141W | Missense Mutation (SNP) | VAF 54/590 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs187063864, CM166200; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- CDKN2A | c.262G>T p.E88* | Nonsense Mutation (SNP) | VAF 246/532 reads (46%) | hotspot (GDC flag); catalogued as rs121913384, CM034218, CM095540, COSV58683071, COSV58683670; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- MYO7A | c.5617C>T p.R1873W | Missense Mutation (SNP) | VAF 114/313 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs397516321, CM064133; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.395A>G p.K132R | Missense Mutation (SNP) | VAF 145/322 reads (45%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs1057519996, COSV52666637, COSV52701687, COSV52759171; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ABCB1 | c.2501C>G p.A834G | Missense Mutation (SNP) | VAF 100/359 reads (28%) | SIFT tolerated (1); PolyPhen probably damaging (0.998); catalogued as COSV55953276; called by muse, mutect2, varscan2
- ABCB4 | c.3507C>A p.H1169Q (on ENST00000265723 / NM_018849.3; = p.H1162Q on NM_000443.4) | Missense Mutation (SNP) | VAF 146/430 reads (34%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV55931639; called by muse, mutect2, varscan2
- ABCB5 | c.1672G>A p.E558K (on ENST00000404938 / NM_001163941.2; = p.E113K on NM_178559.6) | Missense Mutation (SNP) | VAF 40/328 reads (12%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.983); catalogued as rs1562544342; called by muse, varscan2
- ABCB5 | c.2067G>T p.W689C (on ENST00000404938 / NM_001163941.2; = p.W244C on NM_178559.6) | Missense Mutation (SNP) | VAF 12/180 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); catalogued as rs1475291875, COSV51712352; called by muse, mutect2
- AC011005.1 | c.628T>A p.C210S | Missense Mutation (SNP) | VAF 62/466 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as rs758138442; called by muse, mutect2, varscan2
- ADAM2 | c.154G>A p.E52K | Missense Mutation (SNP) | VAF 38/183 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.474); catalogued as rs867879609; called by muse, mutect2, varscan2
- ADAM23 | c.1627G>T p.G543W | Missense Mutation (SNP) | VAF 118/367 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1407664125, COSV52218231; called by muse, mutect2, varscan2
- ADAMTS16 | c.2946C>A p.N982K | Missense Mutation (SNP) | VAF 50/226 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.298); catalogued as rs546888690; called by muse, mutect2, varscan2
- ADAMTS19 | c.1048G>A p.D350N | Missense Mutation (SNP) | VAF 58/197 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.944); catalogued as rs781051430; called by muse, mutect2, varscan2
- ADAMTS2 | c.1744A>T p.K582* | Nonsense Mutation (SNP) | VAF 52/331 reads (16%) | catalogued as rs1371994073; called by muse, mutect2, varscan2
- ADCY1 | c.775G>T p.E259* | Nonsense Mutation (SNP) | VAF 54/202 reads (27%) | catalogued as rs768837270, COSV52043598; called by muse, mutect2
- ADCY2 | c.2585C>T p.A862V | Missense Mutation (SNP) | VAF 39/206 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as rs201452559; called by muse, mutect2, varscan2
- ADCY8 | c.964G>T p.V322L | Missense Mutation (SNP) | VAF 33/223 reads (15%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV53911953; called by muse, mutect2
- ADGRL2 | c.1745C>A p.P582H | Missense Mutation (SNP) | VAF 62/254 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99587149; called by muse, mutect2, varscan2
- ADGRV1 | c.13489C>T p.L4497F | Missense Mutation (SNP) | VAF 112/295 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs1345469409; called by muse, mutect2, varscan2
- ADNP2 | c.3140A>C p.E1047A | Missense Mutation (SNP) | VAF 80/206 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.124); catalogued as COSV100081221; called by muse, mutect2, varscan2
- AFAP1L1 | c.1904C>T p.T635M | Missense Mutation (SNP) | VAF 23/416 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.01); catalogued as rs755708543; called by muse, mutect2
- AGGF1 | c.516+4A>G | Splice Region (SNP) | VAF 82/242 reads (34%) | catalogued as rs1263841186; called by muse, mutect2, varscan2
- AIRE | c.59T>A p.V20E | Missense Mutation (SNP) | VAF 93/274 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as rs1291820513; called by muse, mutect2, varscan2
- ALDH8A1 | c.1239C>A p.N413K | Missense Mutation (SNP) | VAF 47/591 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1189723285; called by muse, mutect2
- ALK | c.4397C>A p.P1466H | Missense Mutation (SNP) | VAF 51/103 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.079); catalogued as rs1368483124, COSV66595297; called by muse, mutect2, varscan2
- ALK | c.2219G>T p.G740V | Missense Mutation (SNP) | VAF 20/137 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV66565262; called by muse, mutect2
- AMER1 | c.2074G>T p.E692* | Nonsense Mutation (SNP) | VAF 81/365 reads (22%) | catalogued as COSV100367201; called by muse, mutect2, varscan2
- AMER3 | c.1258G>C p.D420H | Missense Mutation (SNP) | VAF 70/149 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58466467; called by muse, mutect2, varscan2
- ANK1 | c.4071C>A p.C1357* | Nonsense Mutation (SNP) | VAF 128/506 reads (25%) | catalogued as COSV55872557; called by muse, mutect2, varscan2
- ANK1 | c.2761G>T p.A921S | Missense Mutation (SNP) | VAF 199/722 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55883130; called by muse, mutect2, varscan2
- ANKRD13B | c.1829A>G p.Q610R | Missense Mutation (SNP) | VAF 42/173 reads (24%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs965673973; called by muse, mutect2, varscan2
- ANO4 | c.859A>C p.T287P (on ENST00000392977 / NM_001286615.2; = p.T252P on NM_178826.4) | Missense Mutation (SNP) | VAF 28/281 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.058); catalogued as rs747732523; called by muse, mutect2, varscan2
- APC | c.1591G>T p.A531S | Missense Mutation (SNP) | VAF 188/606 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV57340990; called by muse, mutect2, varscan2
- ARPP21 | c.1366C>A p.Q456K | Missense Mutation (SNP) | VAF 210/540 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.626); catalogued as COSV51797853; called by muse, mutect2, varscan2
- ASB15 | c.1084G>T p.D362Y | Missense Mutation (SNP) | VAF 68/178 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs758601099; called by muse, mutect2, varscan2
- ASIC2 | c.1492G>A p.V498M | Missense Mutation (SNP) | VAF 117/412 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.148); catalogued as rs747699019; called by muse, mutect2, varscan2
- ASL | c.919-4G>T | Splice Region (SNP) | VAF 140/480 reads (29%) | catalogued as rs756230523; called by muse, mutect2, varscan2
- ASL | c.1195G>T p.E399* | Nonsense Mutation (SNP) | VAF 192/584 reads (33%) | catalogued as COSV59188636, COSV59190049; called by muse, mutect2, varscan2
- ASZ1 | c.371C>T p.S124L | Missense Mutation (SNP) | VAF 22/150 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.024); catalogued as rs762514505; called by muse, mutect2, varscan2
- ATP12A | c.2134C>A p.Q712K | Missense Mutation (SNP) | VAF 143/253 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54518542; called by muse, mutect2, varscan2
- ATXN2 | c.1395G>T p.R465S (on ENST00000550104; = p.R305S on NM_002973.4) | Missense Mutation (SNP) | VAF 285/611 reads (47%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.994); catalogued as rs1555235247; called by muse, mutect2, varscan2
- ATXN2L | c.833+1G>A p.X278_splice | Splice Site (SNP) | VAF 8/154 reads (5%) | catalogued as rs1241144522; called by muse, mutect2
- AXIN1 | c.1429C>T p.R477C | Missense Mutation (SNP) | VAF 201/408 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1185544639; called by muse, mutect2, varscan2
- B4GALNT3 | c.1894G>T p.V632L | Missense Mutation (SNP) | VAF 220/1152 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as COSV56751064; called by muse, mutect2, varscan2
- BDKRB2 | c.1112G>C p.R371P | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); catalogued as COSV60015335; called by muse, mutect2
- BEX1 | c.316C>G p.R106G | Missense Mutation (SNP) | VAF 71/236 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.733); catalogued as COSV65580771; called by muse, mutect2, varscan2
- BICD1 | c.1078G>T p.A360S | Missense Mutation (SNP) | VAF 116/305 reads (38%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as rs1565673246, COSV99863162; called by muse, mutect2, varscan2
- BMPER | c.965G>T p.C322F | Missense Mutation (SNP) | VAF 100/811 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs528496792; called by muse, mutect2, varscan2
- BOD1L1 | c.7745A>T p.H2582L | Missense Mutation (SNP) | VAF 100/216 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.026); catalogued as COSV50035483; called by muse, mutect2, varscan2
- BRINP3 | c.2081G>C p.G694A | Missense Mutation (SNP) | VAF 107/231 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.368); catalogued as COSV66544173; called by muse, mutect2, varscan2
- BRWD1 | c.1717A>C p.N573H | Missense Mutation (SNP) | VAF 80/294 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.314); catalogued as rs1484622549; called by muse, mutect2, varscan2
- BSND | c.77T>A p.M26K | Missense Mutation (SNP) | VAF 94/292 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as COSV64870792; called by muse, mutect2, varscan2
- C6orf118 | c.290C>A p.P97Q | Missense Mutation (SNP) | VAF 62/129 reads (48%) | SIFT tolerated (0.42); PolyPhen benign (0.007); catalogued as rs775322305, COSV57817690; called by muse, mutect2, varscan2
- C8A | c.1396G>T p.E466* | Nonsense Mutation (SNP) | VAF 122/333 reads (37%) | catalogued as rs754227627; called by muse, mutect2, varscan2
- CACNA1B | c.3833C>G p.S1278C | Missense Mutation (SNP) | VAF 45/112 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99498107; called by muse, mutect2, varscan2
- CACNA1B | c.6869G>T p.R2290L | Missense Mutation (SNP) | VAF 87/239 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.501); catalogued as rs76756995, COSV53154042; called by muse, mutect2, varscan2
- CACNG7 | c.296C>A p.T99K | Missense Mutation (SNP) | VAF 76/204 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.036); catalogued as COSV55813458; called by muse, mutect2, varscan2
- CANX | c.233G>A p.G78E | Missense Mutation (SNP) | VAF 122/267 reads (46%) | SIFT tolerated (0.13); PolyPhen benign (0.176); catalogued as rs765797003; called by muse, mutect2, varscan2
- CAPN6 | c.692C>A p.S231Y | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.819); catalogued as rs1569481016; called by muse, mutect2, varscan2
- CARD10 | c.1139G>T p.R380L | Missense Mutation (SNP) | VAF 104/359 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.354); catalogued as rs1363325325; called by muse, mutect2, varscan2
- CASP5 | c.269A>C p.H90P | Missense Mutation (SNP) | VAF 31/416 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.313); catalogued as COSV52828346; called by muse, mutect2
- CAVIN1 | c.1066G>T p.G356W | Missense Mutation (SNP) | VAF 70/144 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs552276447, COSV63812387; called by muse, mutect2, varscan2
- CCDC57 | c.2725C>T p.R909C | Missense Mutation (SNP) | VAF 54/122 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs558941844, COSV100148548, COSV60752741; called by muse, mutect2, varscan2
- CCDC62 | c.1981C>A p.L661I | Missense Mutation (SNP) | VAF 16/237 reads (7%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.009); catalogued as COSV53431316; called by muse, mutect2
- CCL21 | c.136C>G p.R46G | Missense Mutation (SNP) | VAF 117/290 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.871); catalogued as rs1453433779; called by muse, mutect2, varscan2
- CCT5 | c.1060G>T p.G354C | Missense Mutation (SNP) | VAF 100/448 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54725169; called by mutect2, varscan2
- CD226 | c.631G>T p.D211Y | Missense Mutation (SNP) | VAF 129/396 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as COSV99711430; called by muse, varscan2
- CD226 | c.511C>T p.R171C | Missense Mutation (SNP) | VAF 128/467 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.024); catalogued as rs751925448, COSV99711312; called by muse, varscan2
- CD79A | c.156C>G p.F52L | Missense Mutation (SNP) | VAF 43/325 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55737901; called by muse, mutect2, varscan2
- CDC14C | c.488C>A p.S163Y (on ENST00000428251; = p.S56Y on NM_152627.3) | Missense Mutation (SNP) | VAF 36/282 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1239861757; called by muse, mutect2, varscan2
- CDC73 | c.594G>T p.K198N | Missense Mutation (SNP) | VAF 191/499 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as COSV66467984; called by muse, mutect2, varscan2
- CDH22 | c.32G>T p.R11L | Missense Mutation (SNP) | VAF 135/336 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.014); catalogued as rs1243952156; called by muse, varscan2
- CDH9 | c.1688C>T p.T563I | Missense Mutation (SNP) | VAF 91/438 reads (21%) | SIFT tolerated (0.3); PolyPhen benign (0.013); catalogued as COSV50257873; called by muse, mutect2, varscan2
- CEMIP2 | c.425G>C p.R142P | Missense Mutation (SNP) | VAF 28/337 reads (8%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.959); catalogued as rs200303233; called by muse, mutect2
- CENPJ | c.60G>C p.W20C | Missense Mutation (SNP) | VAF 114/210 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV67884219; called by muse, mutect2, varscan2
- CFAP47 | c.2818G>C p.A940P | Missense Mutation (SNP) | VAF 28/383 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.443); catalogued as rs754210036, COSV52883872, COSV52892724, COSV99935401; called by muse, mutect2
- CHML | c.1631C>A p.T544K | Missense Mutation (SNP) | VAF 16/161 reads (10%) | SIFT tolerated (0.49); PolyPhen benign (0.023); catalogued as rs767840796; called by muse, mutect2
- CHODL | c.328C>A p.Q110K | Missense Mutation (SNP) | VAF 51/153 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0.233); catalogued as COSV54734574; called by muse, mutect2, varscan2
- CHRNA4 | c.998G>T p.R333L | Missense Mutation (SNP) | VAF 127/1097 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64718624; called by muse, mutect2, varscan2
- CILP2 | c.1158C>A p.D386E | Missense Mutation (SNP) | VAF 30/53 reads (57%) | SIFT deleterious (0.02); PolyPhen benign (0.044); catalogued as COSV52277967; called by muse, mutect2, varscan2
- CLCA4 | c.736-1G>T p.X246_splice | Splice Site (SNP) | VAF 5/60 reads (8%) | catalogued as rs955974655, COSV99760823; called by muse, mutect2
- CLEC1B | c.176G>T p.R59L | Missense Mutation (SNP) | VAF 118/323 reads (37%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs751872895, COSV100046183; called by muse, mutect2, varscan2
- CLTCL1 | c.1618G>A p.E540K | Missense Mutation (SNP) | VAF 186/653 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.228); catalogued as rs927569939; called by muse, mutect2, varscan2
- CNTLN | c.1846G>T p.A616S | Missense Mutation (SNP) | VAF 128/326 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.485); catalogued as COSV52066328; called by muse, mutect2, varscan2
- CNTNAP5 | c.1304G>T p.R435L | Missense Mutation (SNP) | VAF 75/171 reads (44%) | SIFT tolerated (0.41); PolyPhen benign (0.058); catalogued as COSV70496411, COSV70507161; called by muse, mutect2, varscan2
- COBL | c.35C>G p.P12R | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.993); catalogued as rs1422252021; called by muse, mutect2, varscan2
- COL12A1 | c.6951C>A p.C2317* | Nonsense Mutation (SNP) | VAF 6/70 reads (9%) | catalogued as COSV59393335; called by muse, mutect2
- COL12A1 | c.5664G>T p.L1888= | Splice Region (SNP) | VAF 18/206 reads (9%) | catalogued as COSV100485188; called by muse, mutect2
- COL19A1 | c.1253G>T p.G418V | Missense Mutation (SNP) | VAF 108/396 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.154); catalogued as COSV59565823, COSV59582426; called by muse, mutect2, varscan2
- COL22A1 | c.4219C>A p.P1407T | Missense Mutation (SNP) | VAF 58/612 reads (9%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.446); catalogued as rs1013663362, COSV57338966; called by muse, mutect2
- COL22A1 | c.2247G>A p.T749= | Splice Region (SNP) | VAF 108/325 reads (33%) | catalogued as rs1488912395; called by muse, mutect2, varscan2
- COL24A1 | c.478G>A p.D160N | Missense Mutation (SNP) | VAF 16/260 reads (6%) | SIFT tolerated (0.27); PolyPhen benign (0.061); catalogued as rs1320375371, COSV65305903; called by muse, mutect2
- COL4A4 | c.1032G>T p.G344= | Splice Region (SNP) | VAF 199/575 reads (35%) | catalogued as rs748362844; called by muse, mutect2, varscan2
- COL6A5 | c.7576C>G p.L2526V (on ENST00000312481; = p.L2522V on NM_153264.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 37/110 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.014); catalogued as COSV99594823; called by muse, mutect2, varscan2
- COL9A2 | c.364-4C>T | Splice Region (SNP) | VAF 127/392 reads (32%) | catalogued as rs1276761247; called by muse, mutect2, varscan2
- CPEB4 | c.1925G>T p.R642L | Missense Mutation (SNP) | VAF 36/68 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54176346; called by muse, mutect2, varscan2
- CPS1 | c.737C>G p.P246R | Missense Mutation (SNP) | VAF 29/347 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51801482; called by muse, mutect2
- CPXM1 | c.1159C>T p.R387W | Missense Mutation (SNP) | VAF 40/386 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs976579617; called by muse, mutect2
- CREBBP | c.4728+1G>T p.X1576_splice | Splice Site (SNP) | VAF 226/507 reads (45%) | catalogued as CS065532, COSV52122377; called by muse, mutect2, varscan2
- CRISPLD1 | c.13G>T p.A5S | Missense Mutation (SNP) | VAF 37/160 reads (23%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as rs1165616521, COSV51551479; called by muse, mutect2, varscan2
- CSMD1 | c.5293C>G p.R1765G (on ENST00000520002; = p.R1764G on NM_033225.6) | Missense Mutation (SNP) | VAF 211/514 reads (41%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as COSV59298786; called by muse, mutect2, varscan2
- CSMD3 | c.944C>A p.P315Q | Missense Mutation (SNP) | VAF 100/351 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV52252359; called by muse, mutect2, varscan2
- CTNNA3 | c.1891G>T p.E631* | Nonsense Mutation (SNP) | VAF 72/402 reads (18%) | catalogued as COSV65563977; called by mutect2, varscan2
- CTNNA3 | c.182C>T p.S61F | Missense Mutation (SNP) | VAF 111/454 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV57719565; called by muse, mutect2, varscan2
- CTTN | c.436G>C p.E146Q | Missense Mutation (SNP) | VAF 94/394 reads (24%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.836); catalogued as rs939803104; called by muse, mutect2, varscan2
- CTTNBP2 | c.3797G>A p.R1266H | Missense Mutation (SNP) | VAF 50/565 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs200782612, COSV50392485; called by muse, mutect2
- CUBN | c.10412G>T p.G3471V | Missense Mutation (SNP) | VAF 340/775 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV64723307; called by muse, mutect2, varscan2
- CUX2 | c.2695C>A p.L899M | Missense Mutation (SNP) | VAF 64/134 reads (48%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.94); catalogued as COSV99918991; called by muse, mutect2, varscan2
- CWC22 | c.383G>A p.R128H | Missense Mutation (SNP) | VAF 149/496 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.157); catalogued as rs538460267, COSV55427111, COSV55430619; called by muse, mutect2, varscan2
- CXorf65 | c.208C>G p.R70G | Missense Mutation (SNP) | VAF 32/150 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV52147725, COSV99340227; called by muse, mutect2, varscan2
- DACT1 | c.496G>A p.D166N | Missense Mutation (SNP) | VAF 70/255 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60023995; called by muse, mutect2, varscan2
- DAOA | c.105C>G p.S35R | Missense Mutation (SNP) | VAF 63/165 reads (38%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as rs757545454; called by muse, mutect2, varscan2
- DCC | c.2510T>G p.V837G | Missense Mutation (SNP) | VAF 118/353 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV59103145; called by muse, mutect2, varscan2
- DCDC2 | c.1207C>T p.R403C | Missense Mutation (SNP) | VAF 62/595 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); catalogued as rs1244351893, COSV65829420; called by muse, mutect2, varscan2
- DCHS1 | c.1517G>A p.G506D | Missense Mutation (SNP) | VAF 137/376 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770588802; called by muse, mutect2, varscan2
- DDX53 | c.139C>G p.R47G | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT tolerated (0.34); PolyPhen benign (0.012); catalogued as COSV60068512; called by muse, mutect2, varscan2
- DHX9 | c.3053G>T p.R1018L | Missense Mutation (SNP) | VAF 203/457 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.71); catalogued as COSV62358627; called by muse, mutect2, varscan2
- DLG2 | c.136G>T p.E46* | Nonsense Mutation (SNP) | VAF 56/659 reads (8%) | catalogued as COSV101074484, COSV65860536; called by muse, mutect2
- DLX3 | c.833G>C p.G278A | Missense Mutation (SNP) | VAF 153/295 reads (52%) | SIFT tolerated (0.19); PolyPhen benign (0.039); catalogued as COSV71548019; called by muse, mutect2, varscan2
- DNAH7 | c.1353G>T p.W451C | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.706); catalogued as COSV56754570; called by muse, mutect2, varscan2
- DNAH8 | c.5174C>A p.T1725N | Missense Mutation (SNP) | VAF 26/338 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV59430875; called by muse, mutect2
- DNAH9 | c.4261C>T p.R1421W | Missense Mutation (SNP) | VAF 348/723 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs763130440, COSV52339615; called by muse, mutect2, varscan2
- DNM1 | c.777C>A p.F259L | Missense Mutation (SNP) | VAF 111/279 reads (40%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.992); catalogued as COSV57855827; called by muse, mutect2, varscan2
- DNM1 | c.2308G>T p.A770S | Missense Mutation (SNP) | VAF 50/104 reads (48%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV57849689; called by muse, mutect2, varscan2
- DOP1B | c.3535G>T p.V1179L | Missense Mutation (SNP) | VAF 61/217 reads (28%) | SIFT tolerated (0.42); PolyPhen benign (0.034); catalogued as rs766136017; called by muse, mutect2, varscan2
- DPY30 | c.56C>G p.S19C | Missense Mutation (SNP) | VAF 95/467 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.258); catalogued as COSV54458968; called by muse, mutect2, varscan2
- DSCAML1 | c.5957G>A p.R1986H (on ENST00000321322; = p.R1926H on NM_020693.4) | Missense Mutation (SNP) | VAF 259/542 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.817); catalogued as rs747929470; called by muse, mutect2, varscan2
- DTNA | c.1786G>T p.G596* | Nonsense Mutation (SNP) | VAF 185/546 reads (34%) | catalogued as COSV52014973; called by muse, mutect2, varscan2
- DYSF | c.2895G>T p.W965C | Missense Mutation (SNP) | VAF 241/506 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99251091; called by muse, mutect2, varscan2
- DZIP3 | c.1153A>G p.I385V | Missense Mutation (SNP) | VAF 28/88 reads (32%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.001); catalogued as rs1323202468; called by muse, mutect2
- E2F3 | c.810G>T p.E270D | Missense Mutation (SNP) | VAF 147/400 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.517); catalogued as COSV60896748; called by muse, mutect2, varscan2
- EIF2AK1 | c.760C>G p.L254V | Missense Mutation (SNP) | VAF 115/355 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.075); catalogued as COSV52245566; called by muse, mutect2, varscan2
- ELAVL2 | c.489C>G p.G163= | Splice Region (SNP) | VAF 60/158 reads (38%) | catalogued as COSV56365624; called by muse, varscan2
- ELAVL4 | c.289C>T p.P97S | Missense Mutation (SNP) | VAF 52/143 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0.035); catalogued as COSV63915776; called by muse, mutect2, varscan2
- EPHA3 | c.1032C>G p.D344E | Missense Mutation (SNP) | VAF 80/241 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.044); catalogued as COSV100341781; called by muse, mutect2, varscan2
- EPHB6 | c.1751-4C>A | Splice Region (SNP) | VAF 260/691 reads (38%) | catalogued as rs560317400; called by muse, mutect2, varscan2
- ESYT2 | c.1136G>T p.R379L (on ENST00000613624; = p.R303L on NM_020728.3) | Missense Mutation (SNP) | VAF 28/161 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV51749013, COSV51756836; called by muse, mutect2, varscan2
- ETFA | c.53G>T p.R18L | Missense Mutation (SNP) | VAF 214/556 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV51211380; called by muse, mutect2, varscan2
- ETV3L | c.586G>A p.G196R | Missense Mutation (SNP) | VAF 40/375 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.36); catalogued as rs760285259, COSV71901152; called by muse, mutect2, varscan2
- EYS | c.5425T>A p.S1809T | Missense Mutation (SNP) | VAF 64/710 reads (9%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0.001); catalogued as COSV58196680; called by muse, mutect2
- F9 | c.797C>A p.A266D | Missense Mutation (SNP) | VAF 87/419 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM940584, COSV99496622; called by muse, mutect2, varscan2
- FAM83B | c.1212G>T p.R404S | Missense Mutation (SNP) | VAF 54/295 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.322); catalogued as COSV60921948; called by muse, mutect2, varscan2
- FBN2 | c.555G>C p.Q185H | Missense Mutation (SNP) | VAF 180/553 reads (33%) | SIFT tolerated (0.96); PolyPhen possibly damaging (0.753); catalogued as COSV52534790; called by muse, mutect2, varscan2
- FBP2 | c.472C>T p.R158C | Missense Mutation (SNP) | VAF 94/232 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.086); catalogued as rs759228397; called by muse, mutect2, varscan2
- FBXL7 | c.1085G>T p.R362L | Missense Mutation (SNP) | VAF 22/339 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.074); catalogued as rs1187472492, COSV100309107, COSV61646956; called by muse, mutect2
- FBXO10 | c.131G>T p.R44L | Missense Mutation (SNP) | VAF 141/362 reads (39%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs780121584; called by muse, mutect2, varscan2
- FCRL1 | c.137C>A p.S46* | Nonsense Mutation (SNP) | VAF 44/538 reads (8%) | catalogued as COSV63823888; called by muse, mutect2
- FFAR3 | c.683C>A p.A228E | Missense Mutation (SNP) | VAF 121/1352 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.145); catalogued as rs760108323, COSV100588198; called by muse, mutect2
- FLT1 | c.3443C>A p.A1148E | Missense Mutation (SNP) | VAF 185/400 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.243); catalogued as COSV56739680; called by muse, mutect2, varscan2
- FMN2 | c.1315C>T p.Q439* | Nonsense Mutation (SNP) | VAF 59/243 reads (24%) | catalogued as COSV60434920; called by muse, mutect2, varscan2
- FOLH1 | c.1769C>T p.S590F | Missense Mutation (SNP) | VAF 101/475 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); catalogued as rs866827421, COSV99923017; called by muse, mutect2, varscan2
- FOXG1 | c.1405G>T p.G469W | Missense Mutation (SNP) | VAF 94/509 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.841); catalogued as COSV57396020; called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.463G>C p.E155Q | Missense Mutation (SNP) | VAF 57/309 reads (18%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.233); catalogued as COSV100436063; called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.2007G>T p.K669N | Missense Mutation (SNP) | VAF 33/91 reads (36%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.559); catalogued as COSV58552796; called by muse, mutect2, varscan2
- FRMPD2 | c.517G>T p.G173C | Missense Mutation (SNP) | VAF 43/88 reads (49%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.598); catalogued as rs1473314496; called by muse, mutect2, varscan2
- FSCB | c.1603G>A p.A535T | Missense Mutation (SNP) | VAF 53/199 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.142); catalogued as rs1299270204; called by muse, mutect2, varscan2
- FYB2 | c.382G>T p.E128* | Nonsense Mutation (SNP) | VAF 142/331 reads (43%) | catalogued as COSV58582867; called by muse, mutect2, varscan2
- GABRA2 | c.281G>A p.R94Q | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV62919553; called by muse, mutect2, varscan2
- GALNT8 | c.115G>T p.G39C | Missense Mutation (SNP) | VAF 134/786 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.438); catalogued as COSV52898489; called by muse, mutect2, varscan2
- GANC | c.1188G>C p.W396C | Missense Mutation (SNP) | VAF 254/606 reads (42%) | PolyPhen probably damaging (1); catalogued as COSV100530811; called by muse, mutect2, varscan2
- GCK | c.1253+1G>T p.X418_splice | Splice Site (SNP) | VAF 32/119 reads (27%) | catalogued as CS012209, CS032698; called by muse, varscan2
- GJA8 | c.1165del p.E389Rfs*20 | Frame Shift Del (DEL) | VAF 42/407 reads (10%) | catalogued as COSV99569424; called by mutect2, pindel, varscan2
- GPATCH8 | c.4156G>C p.A1386P | Missense Mutation (SNP) | VAF 57/125 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV59199890; called by muse, mutect2, varscan2
- GPR141 | c.615G>A p.M205I | Missense Mutation (SNP) | VAF 72/194 reads (37%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as COSV57731392; called by muse, mutect2, varscan2
- GPR142 | c.403G>T p.G135W | Missense Mutation (SNP) | VAF 85/180 reads (47%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.021); catalogued as COSV100171057; called by muse, mutect2, varscan2
- GUCY2F | c.2641G>T p.D881Y | Missense Mutation (SNP) | VAF 73/260 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV54299861; called by muse, mutect2, varscan2
- H1-7 | c.425G>A p.R142H | Missense Mutation (SNP) | VAF 44/339 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.049); catalogued as COSV58601602; called by muse, mutect2, varscan2
- H2BC18 | c.25C>T p.P9S | Missense Mutation (SNP) | VAF 307/685 reads (45%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.418); catalogued as COSV100516193; called by muse, mutect2, varscan2
- H3C2 | c.220G>C p.E74Q | Missense Mutation (SNP) | VAF 58/607 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.984); catalogued as COSV52517721, COSV52518221; called by muse, mutect2
- HAO1 | c.493G>T p.G165C | Missense Mutation (SNP) | VAF 85/475 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768618504; called by muse, mutect2, varscan2
- HDAC9 | c.1591A>C p.S531R | Missense Mutation (SNP) | VAF 87/672 reads (13%) | SIFT tolerated (0.34); PolyPhen benign (0.113); catalogued as COSV67779651; called by muse, varscan2
- HDAC9 | c.2630G>T p.G877V | Missense Mutation (SNP) | VAF 53/284 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101288084; called by muse, mutect2, varscan2
- HEATR5A | c.4442G>T p.G1481V | Missense Mutation (SNP) | VAF 38/165 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs771922159; called by muse, mutect2, varscan2
- HEATR5B | c.3941G>T p.G1314V | Missense Mutation (SNP) | VAF 133/320 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51858218; called by muse, mutect2, varscan2
- HFM1 | c.2923G>T p.G975* | Nonsense Mutation (SNP) | VAF 40/110 reads (36%) | catalogued as COSV54025666; called by muse, varscan2
- HFM1 | c.454G>T p.A152S | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.001); catalogued as rs1181511413; called by muse, mutect2, varscan2
- HGSNAT | c.118+1G>T p.X40_splice | Splice Site (SNP) | VAF 39/189 reads (21%) | catalogued as CS065561; called by muse, mutect2, varscan2
- HMCN1 | c.15741C>A p.N5247K | Missense Mutation (SNP) | VAF 80/303 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54919235; called by muse, mutect2, varscan2
- HMGCLL1 | c.483+1G>C p.X161_splice | Splice Site (SNP) | VAF 8/58 reads (14%) | catalogued as COSV51450697; called by muse, varscan2
- HSPA12A | c.1621G>T p.V541L | Missense Mutation (SNP) | VAF 142/259 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); catalogued as COSV65020678; called by muse, mutect2, varscan2
- HSPA14 | c.679G>T p.G227C | Missense Mutation (SNP) | VAF 190/417 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65684078; called by muse, mutect2, varscan2
- HSPG2 | c.11708C>A p.P3903H | Missense Mutation (SNP) | VAF 52/373 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs928883966; called by muse, mutect2, varscan2
- IFT88 | c.704A>G p.N235S (on ENST00000319980 / NM_001318493.2; = p.N226S on NM_006531.5 and 9 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 49/165 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.97); catalogued as rs943898625; called by muse, mutect2, varscan2
- IGLON5 | c.257G>T p.R86L | Missense Mutation (SNP) | VAF 49/228 reads (21%) | SIFT tolerated (0.26); PolyPhen benign (0.111); catalogued as rs762872088; called by muse, mutect2, varscan2
- ILK | c.1275G>A p.M425I | Missense Mutation (SNP) | VAF 170/464 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as rs373728455; called by muse, mutect2, varscan2
- IPO8 | c.1829del p.G610Efs*10 | Frame Shift Del (DEL) | VAF 32/145 reads (22%) | catalogued as rs1565500859; called by mutect2, pindel, varscan2
- IQGAP2 | c.451G>T p.A151S | Missense Mutation (SNP) | VAF 31/128 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.864); catalogued as COSV57177499; called by muse, mutect2, varscan2
- IRF7 | c.989C>G p.P330R (on ENST00000397566; = p.P317R on NM_001572.5) | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.246); catalogued as rs776833814; called by muse, mutect2, varscan2
- ITGB8 | c.2011G>C p.D671H | Missense Mutation (SNP) | VAF 42/291 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.598); catalogued as COSV56005590, COSV56015637; called by muse, mutect2, varscan2
- ITK | c.766A>G p.T256A | Missense Mutation (SNP) | VAF 44/621 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.089); catalogued as rs1379215056; called by muse, mutect2
- ITLN1 | c.496C>A p.L166M | Missense Mutation (SNP) | VAF 59/184 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV58276663; called by muse, mutect2, varscan2
- ITPR1 | c.7058C>T p.T2353M (on ENST00000354582; = p.T2298M on NM_002222.7) | Missense Mutation (SNP) | VAF 8/252 reads (3%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs927887017; called by muse, mutect2
- ITSN1 | c.2347G>T p.G783C | Missense Mutation (SNP) | VAF 41/232 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1156923746, COSV101180456; called by muse, mutect2, varscan2
- JAG2 | c.2209G>C p.A737P | Missense Mutation (SNP) | VAF 85/328 reads (26%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.693); catalogued as COSV100077962; called by muse, mutect2, varscan2
- JPH2 | c.1123C>T p.R375C | Missense Mutation (SNP) | VAF 130/332 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.103); catalogued as rs1199319789, COSV65901949; called by muse, mutect2, varscan2
- KCNB1 | c.2168C>A p.S723Y | Missense Mutation (SNP) | VAF 62/502 reads (12%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.445); catalogued as COSV65570552; called by muse, mutect2, varscan2
- KCNB2 | c.479G>A p.R160Q | Missense Mutation (SNP) | VAF 53/465 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.087); catalogued as COSV73050947, COSV73053233; called by muse, mutect2, varscan2
- KCNH2 | c.3095G>T p.R1032L | Missense Mutation (SNP) | VAF 12/117 reads (10%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.993); catalogued as rs199473020, CM107428; called by muse, mutect2, varscan2
- KCNH2 | c.2145G>T p.A715= | Splice Region (SNP) | VAF 46/386 reads (12%) | catalogued as CS056095; called by muse, mutect2, varscan2
- KCNJ4 | c.1257C>A p.F419L | Missense Mutation (SNP) | VAF 114/318 reads (36%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); catalogued as COSV100341556, COSV57856658; called by muse, mutect2, varscan2
- KCNK16 | c.443G>T p.R148L | Missense Mutation (SNP) | VAF 99/233 reads (42%) | SIFT tolerated (0.27); PolyPhen benign (0.013); catalogued as COSV100949327; called by muse, mutect2, varscan2
- KCNMA1 | c.766C>A p.P256T | Missense Mutation (SNP) | VAF 174/425 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54254270; called by muse, mutect2, varscan2
- KCNS3 | c.997G>T p.V333L | Missense Mutation (SNP) | VAF 240/547 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV58407801; called by muse, mutect2, varscan2
- KEAP1 | c.653A>G p.E218G | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.691); catalogued as COSV50276208; called by muse, mutect2, varscan2
- KHDRBS3 | c.207G>T p.K69N | Missense Mutation (SNP) | VAF 29/152 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.257); catalogued as COSV100878518; called by muse, mutect2, varscan2
- KIF1B | c.1633G>T p.E545* (on ENST00000377086 / NM_001365952.1; = p.E499* on NM_015074.3) | Nonsense Mutation (SNP) | VAF 234/570 reads (41%) | catalogued as COSV55816901; called by muse, mutect2, varscan2
- KLHL33 | c.220C>G p.R74G | Missense Mutation (SNP) | VAF 71/251 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.02); catalogued as COSV100754999, COSV60727056; called by muse, mutect2, varscan2
- KMO | c.598C>A p.P200T | Missense Mutation (SNP) | VAF 16/209 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63808674; called by muse, mutect2
- KRT24 | c.1354G>A p.E452K | Missense Mutation (SNP) | VAF 97/239 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as rs1458494344; called by muse, varscan2
- KRTAP10-8 | c.728C>A p.A243D | Missense Mutation (SNP) | VAF 34/231 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.604); catalogued as rs1336595468; called by muse, mutect2, varscan2
- KRTAP4-5 | c.443G>T p.R148L | Missense Mutation (SNP) | VAF 193/500 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.208); catalogued as COSV100576814; called by muse, mutect2, varscan2
- LAD1 | c.23G>T p.W8L | Missense Mutation (SNP) | VAF 58/403 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1254631208; called by muse, mutect2, varscan2
- LAMA1 | c.3797G>C p.R1266T | Missense Mutation (SNP) | VAF 173/728 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.457); catalogued as COSV67542149; called by muse, mutect2, varscan2
- LAMB1 | c.1114C>T p.R372C | Missense Mutation (SNP) | VAF 52/466 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs964182326, COSV55967862; called by muse, mutect2, varscan2
- LARP4B | c.407C>G p.S136C | Missense Mutation (SNP) | VAF 23/311 reads (7%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.497); catalogued as COSV60222690; called by muse, mutect2
- LATS1 | c.3225C>G p.F1075L | Missense Mutation (SNP) | VAF 27/154 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53597663; called by muse, mutect2, varscan2
- LEFTY2 | c.978G>A p.M326I | Missense Mutation (SNP) | VAF 66/778 reads (8%) | SIFT tolerated (0.25); PolyPhen benign (0.075); catalogued as COSV64746452; called by muse, mutect2
- LHX2 | c.349C>T p.R117C | Missense Mutation (SNP) | VAF 74/177 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.959); catalogued as COSV101010101; called by muse, mutect2, varscan2
- LMTK2 | c.10C>T p.P4S | Missense Mutation (SNP) | VAF 65/165 reads (39%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.06); catalogued as rs1383490341; called by muse, varscan2
- LMX1A | c.872C>A p.T291K | Missense Mutation (SNP) | VAF 68/152 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.522); catalogued as rs370226701; called by muse, mutect2, varscan2
- LRFN5 | c.2095C>A p.P699T | Missense Mutation (SNP) | VAF 80/339 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV53265920; called by muse, mutect2, varscan2
- LRMDA | c.421G>A p.V141M | Missense Mutation (SNP) | VAF 124/312 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.853); catalogued as rs777509370; called by muse, mutect2, varscan2
- LRP1B | c.7623T>A p.D2541E | Missense Mutation (SNP) | VAF 152/426 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67264780; called by muse, mutect2, varscan2
- LRP1B | c.1786G>A p.D596N | Missense Mutation (SNP) | VAF 73/177 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.088); catalogued as COSV101261816; called by muse, mutect2, varscan2
- LRRC1 | c.208G>T p.E70* | Nonsense Mutation (SNP) | VAF 123/392 reads (31%) | catalogued as rs764058874, COSV63824391; called by muse, mutect2, varscan2
- LSAMP | c.93C>A p.S31R | Missense Mutation (SNP) | VAF 146/570 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.866); catalogued as rs1016458460, COSV61301906; called by muse, varscan2
- MAD1L1 | c.1596+1G>T p.X532_splice | Splice Site (SNP) | VAF 35/214 reads (16%) | catalogued as COSV99767179; called by muse, mutect2, varscan2
- MAG | c.142G>T p.D48Y | Missense Mutation (SNP) | VAF 67/225 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV100727951; called by muse, mutect2, varscan2
- MANBA | c.1106C>T p.S369F | Missense Mutation (SNP) | VAF 116/334 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0.062); catalogued as rs1245003808; called by muse, mutect2, varscan2
- MED20 | c.229G>T p.A77S | Missense Mutation (SNP) | VAF 103/311 reads (33%) | SIFT tolerated (0.44); PolyPhen benign (0.11); catalogued as rs963479392, COSV54826491; called by muse, mutect2, varscan2
- METAP1 | c.877G>T p.G293W | Missense Mutation (SNP) | VAF 129/398 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99595674; called by muse, mutect2, varscan2
- MGAM | c.604G>T p.V202L | Missense Mutation (SNP) | VAF 56/438 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV101516582; called by muse, mutect2, varscan2
- MGAT4A | c.401G>A p.G134E | Missense Mutation (SNP) | VAF 110/266 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); catalogued as rs1559165907, COSV53850673; called by muse, mutect2, varscan2
- MLLT11 | c.256G>C p.E86Q | Missense Mutation (SNP) | VAF 58/182 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.713); catalogued as rs1263735277, COSV64461955; called by mutect2, varscan2
- MMP23B | c.16C>G p.R6G | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0.007); catalogued as rs906097776; called by muse, mutect2
- MOS | c.71G>T p.C24F | Missense Mutation (SNP) | VAF 37/104 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs775300184; called by muse, mutect2, varscan2
- MPP1 | c.456G>T p.Q152H | Missense Mutation (SNP) | VAF 55/249 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.321); catalogued as COSV65728035; called by muse, varscan2
- MROH9 | c.1254G>T p.Q418H | Missense Mutation (SNP) | VAF 31/451 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); catalogued as COSV100882622; called by muse, mutect2
- MRPL58 | c.410C>A p.S137Y | Missense Mutation (SNP) | VAF 118/335 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1399023089; called by muse, mutect2, varscan2
- MSR1 | c.1104C>A p.S368R | Missense Mutation (SNP) | VAF 243/492 reads (49%) | SIFT tolerated (0.21); PolyPhen benign (0.029); catalogued as COSV50529985; called by muse, mutect2, varscan2
- MTNR1A | c.745A>G p.I249V | Missense Mutation (SNP) | VAF 137/323 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV56155498; called by muse, mutect2, varscan2
- MTTP | c.2633G>T p.C878F | Missense Mutation (SNP) | VAF 262/614 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55504127; called by muse, varscan2
- MTUS2 | c.768del p.S257Qfs*28 | Frame Shift Del (DEL) | VAF 114/304 reads (38%) | catalogued as COSV70915747; called by mutect2, pindel, varscan2
- MUC12 | c.2033C>A p.A678E (on ENST00000379442; = p.A535E on NM_001164462.1) | Missense Mutation (SNP) | VAF 65/960 reads (7%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.598); catalogued as rs1209748627; called by muse, mutect2
- MUC16 | c.34473G>C p.Q11491H | Missense Mutation (SNP) | VAF 83/161 reads (52%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0.012); catalogued as rs778308500; called by muse, mutect2, varscan2
- MUC17 | c.9695C>A p.T3232K | Missense Mutation (SNP) | VAF 31/194 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs548952598, COSV60282712; called by muse, mutect2, varscan2
- MUC4 | c.13021C>G p.L4341V (on ENST00000463781 / NM_018406.7; = p.L105V on NM_004532.6) | Missense Mutation (SNP) | VAF 22/144 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.099); catalogued as COSV100206501; called by muse, mutect2, varscan2
- MUCL3 | c.346G>A p.E116K | Missense Mutation (SNP) | VAF 26/404 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.242); catalogued as rs1464923621; called by muse, mutect2
- MYLK3 | c.1472C>T p.P491L | Missense Mutation (SNP) | VAF 68/198 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.301); catalogued as rs767239263; called by muse, mutect2, varscan2
- MYO3B | c.1873C>T p.Q625* | Nonsense Mutation (SNP) | VAF 31/343 reads (9%) | catalogued as COSV58702686; called by muse, mutect2
- NAA11 | c.169C>G p.L57V | Missense Mutation (SNP) | VAF 105/253 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1233718153; called by muse, mutect2, varscan2
- NAALAD2 | c.5C>A p.A2E | Missense Mutation (SNP) | VAF 151/402 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.307); catalogued as COSV58966736; called by muse, mutect2, varscan2
- NASP | c.1439C>T p.S480L | Missense Mutation (SNP) | VAF 26/111 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs896757778, COSV63111970; called by muse, mutect2, varscan2
- NAV3 | c.5744G>T p.S1915I (on ENST00000397909 / NM_001024383.2; = p.S1893I on NM_014903.6) | Missense Mutation (SNP) | VAF 99/341 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as rs370402305; called by muse, mutect2, varscan2
- NEIL3 | c.1638G>T p.W546C | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755252807; called by muse, mutect2, varscan2
- NLRP5 | c.839G>T p.R280L | Missense Mutation (SNP) | VAF 129/328 reads (39%) | SIFT tolerated (0.8); PolyPhen benign (0.007); catalogued as rs200653793, COSV66768256; called by muse, mutect2, varscan2
- NLRP7 | c.2333G>A p.W778* (on ENST00000340844 / NM_206828.3; = p.W750* on NM_139176.3) | Nonsense Mutation (SNP) | VAF 13/122 reads (11%) | catalogued as COSV100052734; called by muse, mutect2, varscan2
- NME8 | c.110C>T p.A37V | Missense Mutation (SNP) | VAF 35/578 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as CM142511; called by muse, mutect2
- NOD2 | c.3059G>T p.G1020V | Missense Mutation (SNP) | VAF 235/602 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56049684; called by muse, mutect2, varscan2
- NOX3 | c.510G>T p.R170S | Missense Mutation (SNP) | VAF 75/165 reads (45%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs138528604; called by muse, mutect2, varscan2
- NR4A1 | c.1297G>C p.A433P | Missense Mutation (SNP) | VAF 280/579 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV99671175; called by muse, mutect2, varscan2
- NRXN3 | c.2971G>A p.D991N (on ENST00000335750 / NM_001330195.2; = p.D618N on NM_004796.6) | Missense Mutation (SNP) | VAF 34/148 reads (23%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.991); catalogued as COSV59785961; called by muse, mutect2
- NRXN3 | c.1688G>T p.G563V (on ENST00000557594 / NM_001272020.2; = p.G987V on NM_004796.6) | Missense Mutation (SNP) | VAF 69/273 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV55322487; called by muse, mutect2, varscan2
- OR10AG1 | c.783G>A p.M261I | Missense Mutation (SNP) | VAF 86/454 reads (19%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV100400294; called by muse, mutect2, varscan2
- OR10K1 | c.415G>T p.G139W | Missense Mutation (SNP) | VAF 68/734 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV56872425; called by muse, mutect2
- OR11L1 | c.296C>G p.A99G | Missense Mutation (SNP) | VAF 184/498 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.206); catalogued as COSV63314335; called by muse, mutect2, varscan2
- OR1S2 | c.811G>T p.V271L | Missense Mutation (SNP) | VAF 110/344 reads (32%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.669); catalogued as rs758304516, COSV56920315; called by muse, mutect2, varscan2
- OR2A14 | c.606C>A p.C202* | Nonsense Mutation (SNP) | VAF 310/863 reads (36%) | catalogued as rs571103587, COSV101376439, COSV68718484; called by muse, mutect2, varscan2
- OR2C3 | c.646C>A p.L216M | Missense Mutation (SNP) | VAF 28/222 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as rs1558242103; called by muse, mutect2, varscan2
- OR2M7 | c.200C>T p.S67F | Missense Mutation (SNP) | VAF 26/201 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as rs756006276, COSV58740798; called by muse, mutect2, varscan2
- OR2T1 | c.914G>T p.G305V | Missense Mutation (SNP) | VAF 13/151 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.04); catalogued as COSV63541999; called by muse, mutect2
- OR2T3 | c.851C>A p.T284N | Missense Mutation (SNP) | VAF 108/577 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62083541; called by muse, mutect2, varscan2
- OR4C12 | c.252T>G p.F84L | Missense Mutation (SNP) | VAF 98/295 reads (33%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV100078326; called by muse, mutect2, varscan2
- OR4C15 | c.886C>A p.H296N (on ENST00000314644; = p.H242N on NM_001001920.2) | Missense Mutation (SNP) | VAF 63/247 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.967); catalogued as COSV58952179; called by muse, mutect2, varscan2
- OR4K14 | c.761C>A p.P254H | Missense Mutation (SNP) | VAF 84/347 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59292718; called by muse, mutect2, varscan2
- OR4K14 | c.290G>C p.G97A | Missense Mutation (SNP) | VAF 109/467 reads (23%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.45); catalogued as COSV59294066; called by muse, mutect2, varscan2
- OR4K17 | c.827C>A p.T276N | Missense Mutation (SNP) | VAF 77/381 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.588); catalogued as rs1332380344; called by muse, varscan2
- OR4P4 | c.431T>C p.I144T | Missense Mutation (SNP) | VAF 42/177 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as rs754516549; called by muse, mutect2, varscan2
- OR4X2 | c.288G>T p.L96F | Missense Mutation (SNP) | VAF 119/365 reads (33%) | SIFT tolerated (0.71); PolyPhen benign (0.003); catalogued as rs754246976; called by muse, mutect2, varscan2
- OR5D13 | c.241C>A p.P81T | Missense Mutation (SNP) | VAF 73/330 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); catalogued as COSV62333154; called by muse, mutect2, varscan2
- OR5L2 | c.224C>A p.S75* | Nonsense Mutation (SNP) | VAF 83/309 reads (27%) | catalogued as rs1266368194; called by muse, mutect2, varscan2
- OR5M8 | c.505G>T p.G169C | Missense Mutation (SNP) | VAF 77/312 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59116744; called by muse, mutect2, varscan2
- OR5R1 | c.86G>T p.G29V | Missense Mutation (SNP) | VAF 68/238 reads (29%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as COSV56573758; called by muse, mutect2, varscan2
- OR8H1 | c.403A>T p.M135L | Missense Mutation (SNP) | VAF 46/239 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.607); catalogued as COSV57293314; called by muse, mutect2, varscan2
- OR8K5 | c.728C>G p.S243C | Missense Mutation (SNP) | VAF 67/353 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV57888517; called by muse, mutect2, varscan2
- OR9G1 | c.313G>T p.G105W | Missense Mutation (SNP) | VAF 62/477 reads (13%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as COSV56453317; called by muse, mutect2, varscan2
- OSBPL1A | c.2842G>A p.D948N (on ENST00000319481 / NM_080597.4; = p.D435N on NM_018030.4) | Missense Mutation (SNP) | VAF 30/463 reads (6%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as COSV59111487; called by muse, mutect2
- OTC | c.718-1G>C p.X240_splice | Splice Site (SNP) | VAF 116/869 reads (13%) | catalogued as COSV50004152; called by muse, mutect2, varscan2
- OTOF | c.1712T>C p.L571P | Missense Mutation (SNP) | VAF 81/611 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as rs749724713; called by muse, mutect2, varscan2
- PAM | c.2590G>A p.V864M | Missense Mutation (SNP) | VAF 166/519 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs923300383; called by muse, mutect2, varscan2
- PARD3 | c.2686G>T p.A896S | Missense Mutation (SNP) | VAF 230/591 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs762819451, COSV60745962; called by muse, mutect2, varscan2
- PARG | c.2489G>T p.R830I | Missense Mutation (SNP) | VAF 152/482 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as rs1177193230; called by muse, mutect2, varscan2
- PARP12 | c.1330G>A p.V444I | Missense Mutation (SNP) | VAF 140/504 reads (28%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs768071924, COSV54936600; called by muse, mutect2, varscan2
- PARVB | c.482G>T p.R161L | Missense Mutation (SNP) | VAF 81/184 reads (44%) | SIFT tolerated (0.7); PolyPhen benign (0.069); catalogued as COSV58691384; called by muse, mutect2, varscan2
- PAXBP1 | c.1663G>T p.G555C | Missense Mutation (SNP) | VAF 48/234 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51606798; called by muse, mutect2, varscan2
- PCDH11X | c.1100C>A p.T367K | Missense Mutation (SNP) | VAF 58/261 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV53474828; called by muse, mutect2, varscan2
- PCDH11X | c.2762G>C p.W921S | Missense Mutation (SNP) | VAF 133/510 reads (26%) | SIFT tolerated (1); PolyPhen probably damaging (1); catalogued as COSV53455036; called by muse, mutect2, varscan2
- PCDH15 | c.3161T>A p.M1054K | Missense Mutation (SNP) | VAF 151/501 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.012); catalogued as COSV57308406; called by muse, mutect2, varscan2
- PCDHA13 | c.1449C>A p.D483E | Missense Mutation (SNP) | VAF 228/563 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs926863988, COSV56480859; called by muse, mutect2, varscan2
- PCDHB2 | c.1736C>G p.P579R | Missense Mutation (SNP) | VAF 63/472 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs782299612; called by muse, mutect2, varscan2
- PCDHB7 | c.1491C>A p.H497Q | Missense Mutation (SNP) | VAF 184/533 reads (35%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0.034); catalogued as rs1554280215; called by muse, mutect2, varscan2
- PCDHB8 | c.1539C>G p.H513Q | Missense Mutation (SNP) | VAF 207/1652 reads (13%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.015); catalogued as COSV99177303; called by muse, mutect2, varscan2
- PCDHB9 | c.1856C>T p.A619V | Missense Mutation (SNP) | VAF 172/482 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.65); catalogued as rs782713909; called by muse, mutect2, varscan2
- PCDHGA10 | c.601G>T p.E201* | Nonsense Mutation (SNP) | VAF 102/258 reads (40%) | catalogued as COSV53966962, COSV54011010; called by muse, mutect2, varscan2
- PCDHGA12 | c.1880G>A p.R627H | Missense Mutation (SNP) | VAF 129/357 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.431); catalogued as rs779250544, COSV99341819; called by muse, mutect2, varscan2
- PCDHGB4 | c.1629C>A p.N543K | Missense Mutation (SNP) | VAF 176/487 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as rs749432491; called by muse, mutect2, varscan2
- PCK1 | c.124C>A p.H42N | Missense Mutation (SNP) | VAF 152/458 reads (33%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as rs751329147; called by muse, mutect2, varscan2
- PCLO | c.12701C>A p.A4234E | Missense Mutation (SNP) | VAF 96/349 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1374978628; called by muse, mutect2, varscan2
- PCNX4 | c.1086A>G p.I362M (on ENST00000406854 / NM_001330177.2; = p.I128M on NM_022495.5) | Missense Mutation (SNP) | VAF 67/316 reads (21%) | SIFT tolerated (0.74); PolyPhen benign (0.001); catalogued as rs1031014866, COSV100471136; called by muse, mutect2, varscan2
- PDE4DIP | c.5590A>G p.I1864V | Missense Mutation (SNP) | VAF 24/518 reads (5%) | SIFT tolerated (0.55); PolyPhen benign (0.023); catalogued as COSV57696943; called by muse, mutect2
- PDGFRA | c.2741G>A p.R914Q | Missense Mutation (SNP) | VAF 46/718 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1428997941, COSV99957064; ClinVar: uncertain significance; called by muse, mutect2
- PDLIM2 | c.968G>T p.R323L (on ENST00000397760; = p.R573L on NM_021630.6) | Missense Mutation (SNP) | VAF 141/307 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.031); catalogued as COSV56133849, COSV99747790; called by muse, mutect2, varscan2
- PEG3 | c.1699G>T p.V567L | Missense Mutation (SNP) | VAF 59/254 reads (23%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.992); catalogued as COSV99687955; called by muse, mutect2, varscan2
- PHKA1 | c.1750G>T p.A584S | Missense Mutation (SNP) | VAF 75/372 reads (20%) | SIFT tolerated (0.54); PolyPhen benign (0.086); catalogued as rs868924449; called by muse, mutect2, varscan2
- PHLDB2 | c.1205C>T p.S402L | Missense Mutation (SNP) | VAF 39/308 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV67314531; called by muse, mutect2, varscan2
- PIEZO1 | c.3937G>A p.D1313N | Missense Mutation (SNP) | VAF 21/98 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.526); catalogued as rs267604679; called by muse, mutect2, varscan2
- PIK3AP1 | c.913C>A p.L305M | Missense Mutation (SNP) | VAF 153/526 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV104411753; called by muse, mutect2, varscan2
- PIKFYVE | c.2237G>C p.R746P | Missense Mutation (SNP) | VAF 133/328 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV52247561; called by muse, mutect2, varscan2
- PITPNM1 | c.407G>A p.R136H | Missense Mutation (SNP) | VAF 55/163 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs760327436, COSV56873424; called by muse, mutect2, varscan2
- PLA2G2E | c.308G>A p.R103Q | Missense Mutation (SNP) | VAF 32/230 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.009); catalogued as rs147846234, COSV100908831; called by muse, mutect2, varscan2
- PLEC | c.1774G>A p.D592N (on ENST00000322810 / NM_201380.4; = p.D482N on NM_000445.5) | Missense Mutation (SNP) | VAF 94/573 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs576247373; called by muse, mutect2, varscan2
- PLK1 | c.1688G>C p.R563P | Missense Mutation (SNP) | VAF 160/331 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.124); catalogued as COSV55620775; called by muse, mutect2, varscan2
- PLXNA3 | c.1997G>A p.R666H | Missense Mutation (SNP) | VAF 27/112 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as rs143007606; called by muse, mutect2, varscan2
- PLXNA4 | c.1076T>C p.I359T | Missense Mutation (SNP) | VAF 34/480 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1248514927; called by muse, mutect2
- POM121L12 | c.460C>A p.P154T | Missense Mutation (SNP) | VAF 36/223 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.071); catalogued as COSV68692858; called by muse, mutect2, varscan2
- POM121L12 | c.461C>A p.P154H | Missense Mutation (SNP) | VAF 33/220 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.452); catalogued as rs767476421, COSV101374867; called by muse, mutect2, varscan2
- POM121L2 | c.773G>T p.S258I | Missense Mutation (SNP) | VAF 113/297 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1395124027; called by muse, mutect2, varscan2
- POTEC | c.85del p.H29Tfs*26 | Frame Shift Del (DEL) | VAF 145/643 reads (23%) | catalogued as COSV62800522, COSV62804963; called by mutect2, pindel, varscan2
- PPARD | c.1136G>T p.R379L | Missense Mutation (SNP) | VAF 183/440 reads (42%) | SIFT tolerated (0.14); PolyPhen benign (0.095); catalogued as COSV100283372; called by muse, mutect2, varscan2
- PPFIA4 | c.3434C>T p.P1145L (on ENST00000447715; = p.P1146L on NM_001304331.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1429089497, COSV99690945; called by muse, mutect2, varscan2
- PPP1R21 | c.127G>T p.E43* | Nonsense Mutation (SNP) | VAF 54/313 reads (17%) | catalogued as rs776859680; called by muse, mutect2, varscan2
- PPP1R26 | c.133G>T p.A45S | Missense Mutation (SNP) | VAF 71/200 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.859); catalogued as rs776739888; called by muse, varscan2
- PPP1R32 | c.574G>T p.D192Y | Missense Mutation (SNP) | VAF 56/263 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV58545799; called by muse, mutect2, varscan2
- PRAME | c.245C>T p.P82L | Missense Mutation (SNP) | VAF 107/511 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1197901120; called by muse, mutect2, varscan2
- PREX1 | c.2632G>T p.G878C | Missense Mutation (SNP) | VAF 38/87 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64248032, COSV64251237; called by muse, mutect2, varscan2
- PREX1 | c.1129del p.A377Qfs*21 | Frame Shift Del (DEL) | VAF 146/466 reads (31%) | catalogued as COSV64254433; called by mutect2, pindel, varscan2
- PRH2 | c.496C>T p.Q166* | Nonsense Mutation (SNP) | VAF 22/159 reads (14%) | catalogued as rs1258093581; called by muse, mutect2, varscan2
- PRKAR2B | c.382G>T p.D128Y | Missense Mutation (SNP) | VAF 8/145 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); catalogued as COSV55924876; called by muse, mutect2
- PRKCG | c.370C>T p.L124F | Missense Mutation (SNP) | VAF 67/386 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.497); catalogued as COSV54730170; called by muse, mutect2, varscan2
- PRKRA | c.170C>G p.S57C | Missense Mutation (SNP) | VAF 164/933 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.015); catalogued as COSV57867787; called by muse, mutect2, varscan2
- PRR16 | c.464G>T p.R155L (on ENST00000407149 / NM_001300783.2; = p.R132L on NM_016644.2) | Missense Mutation (SNP) | VAF 75/317 reads (24%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.91); catalogued as COSV65394805; called by muse, mutect2, varscan2
- PRR23B | c.81G>T p.K27N | Missense Mutation (SNP) | VAF 75/226 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1250693786; called by muse, mutect2, varscan2
- PRR36 | c.1798C>T p.Q600* | Nonsense Mutation (SNP) | VAF 71/146 reads (49%) | catalogued as COSV101607141; called by muse, mutect2, varscan2
- PSD2 | c.1823C>A p.P608Q | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT tolerated (0.35); PolyPhen benign (0.262); catalogued as COSV99217014; called by muse, varscan2
- PTGDR2 | c.535C>A p.R179S | Missense Mutation (SNP) | VAF 137/500 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs560069216; called by muse, mutect2, varscan2
- PTH2R | c.739C>A p.L247M | Missense Mutation (SNP) | VAF 96/227 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.951); catalogued as COSV55919758; called by muse, mutect2, varscan2
- PTK7 | c.1060G>T p.V354L | Missense Mutation (SNP) | VAF 68/160 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.134); catalogued as COSV57846106, COSV57850276; called by muse, mutect2, varscan2
- PTPRC | c.330del p.T111Rfs*56 | Frame Shift Del (DEL) | VAF 217/607 reads (36%) | catalogued as COSV61408109; called by mutect2, pindel, varscan2
- PTPRO | c.4G>T p.G2W | Missense Mutation (SNP) | VAF 186/596 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV55518304; called by muse, mutect2, varscan2
- PTPRT | c.3905A>T p.E1302V | Missense Mutation (SNP) | VAF 87/522 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV62034326; called by muse, mutect2, varscan2
- PTPRT | c.369C>A p.Y123* | Nonsense Mutation (SNP) | VAF 134/344 reads (39%) | catalogued as COSV61962000; called by muse, mutect2, varscan2
- PTRHD1 | c.58G>A p.A20T | Missense Mutation (SNP) | VAF 287/439 reads (65%) | SIFT tolerated (0.08); PolyPhen benign (0.036); catalogued as rs1231666592; called by muse, mutect2, varscan2
- PYGL | c.1768+1G>T p.X590_splice | Splice Site (SNP) | VAF 121/525 reads (23%) | catalogued as CS982338, COSV53584481; called by muse, mutect2, varscan2
- RAE1 | c.593A>T p.E198V | Missense Mutation (SNP) | VAF 143/400 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.283); catalogued as COSV64798110; called by muse, mutect2, varscan2
- RASSF2 | c.938G>A p.R313Q | Missense Mutation (SNP) | VAF 22/436 reads (5%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs369987339; called by muse, mutect2
- RASSF8 | c.235C>T p.R79* | Nonsense Mutation (SNP) | VAF 45/270 reads (17%) | catalogued as rs1157741952, COSV51452873; called by muse, mutect2, varscan2
- RBCK1 | c.601G>T p.G201W (on ENST00000356286 / NM_031229.4; = p.G159W on NM_006462.6) | Missense Mutation (SNP) | VAF 89/170 reads (52%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.883); catalogued as rs979362975; called by muse, mutect2, varscan2
- RBL1 | c.109G>A p.E37K | Missense Mutation (SNP) | VAF 48/275 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.052); catalogued as rs376813724; called by muse, mutect2, varscan2
- RBMXL3 | c.278G>T p.R93L | Missense Mutation (SNP) | VAF 31/113 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.166); catalogued as rs1556556314, COSV57755799; called by muse, mutect2, varscan2
- RD3 | c.22C>T p.R8W | Missense Mutation (SNP) | VAF 139/452 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as rs142307843; called by muse, mutect2, varscan2
- RESF1 | c.1501G>C p.D501H | Missense Mutation (SNP) | VAF 96/519 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.104); catalogued as COSV57019269; called by muse, mutect2, varscan2
- RFX1 | c.1304C>T p.S435L | Missense Mutation (SNP) | VAF 46/83 reads (55%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.989); catalogued as rs1186789874, COSV99586225; called by muse, mutect2, varscan2
- RGSL1 | c.1297T>A p.C433S | Missense Mutation (SNP) | VAF 148/468 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs905582494; called by muse, mutect2, varscan2
- RIC3 | c.23G>C p.R8T | Missense Mutation (SNP) | VAF 94/234 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.503); catalogued as COSV99046624; called by muse, mutect2, varscan2
- RINT1 | c.1000G>T p.E334* | Nonsense Mutation (SNP) | VAF 33/66 reads (50%) | catalogued as COSV57559355; called by muse, mutect2, varscan2
- RP1 | c.566A>T p.E189V | Missense Mutation (SNP) | VAF 218/787 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.09); catalogued as COSV55113552; called by muse, mutect2, varscan2
- RP1L1 | c.6456T>A p.D2152E | Missense Mutation (SNP) | VAF 231/518 reads (45%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV66751660; called by muse, mutect2, varscan2
- RPS6KC1 | c.2881G>A p.D961N | Missense Mutation (SNP) | VAF 26/450 reads (6%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.753); catalogued as COSV100873797, COSV100874115; called by muse, mutect2
- RREB1 | c.4291G>T p.A1431S | Missense Mutation (SNP) | VAF 105/238 reads (44%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs750694102; called by muse, mutect2, varscan2
- RTP5 | c.1072G>A p.D358N | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.43); PolyPhen benign (0.216); catalogued as rs763603406, COSV58322447; called by muse, mutect2, varscan2
- RWDD1 | c.667C>G p.L223V | Missense Mutation (SNP) | VAF 66/336 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.1); catalogued as COSV100888264; called by muse, varscan2
- RYR2 | c.11562T>G p.F3854L | Missense Mutation (SNP) | VAF 28/108 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV63712875; called by muse, mutect2, varscan2
- RYR2 | c.13382A>T p.K4461M | Missense Mutation (SNP) | VAF 126/355 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.954); catalogued as COSV100773179, COSV100773532; called by muse, varscan2
- RYR2 | c.13841G>T p.G4614V | Missense Mutation (SNP) | VAF 40/462 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63697907; called by muse, mutect2
- SBF2 | c.4828G>A p.D1610N | Missense Mutation (SNP) | VAF 129/306 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.089); catalogued as COSV99813738; called by muse, mutect2, varscan2
- SBNO2 | c.2858G>T p.R953L | Missense Mutation (SNP) | VAF 52/146 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as COSV62322211; called by muse, mutect2, varscan2
- SCN10A | c.502G>A p.A168T | Missense Mutation (SNP) | VAF 91/276 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.515); catalogued as rs765812732, COSV101479556, COSV71861703; called by muse, mutect2, varscan2
- SCN11A | c.1875C>G p.C625W | Missense Mutation (SNP) | VAF 106/246 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV56578494; called by muse, mutect2, varscan2
- SCNN1A | c.1796G>C p.G599A | Missense Mutation (SNP) | VAF 197/541 reads (36%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs72657540; called by muse, mutect2, varscan2
- SDK1 | c.5094G>T p.E1698D | Missense Mutation (SNP) | VAF 23/213 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as COSV67354634; called by muse, mutect2, varscan2
- SEH1L | c.131G>T p.S44I | Missense Mutation (SNP) | VAF 35/264 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.163); catalogued as rs761546237; called by muse, mutect2, varscan2
- SERAC1 | c.739-1G>T p.X247_splice | Splice Site (SNP) | VAF 72/325 reads (22%) | catalogued as COSV100894908; called by muse, mutect2, varscan2
- SERPINC1 | c.1015T>C p.W339R | Missense Mutation (SNP) | VAF 19/180 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV62929803; called by muse, mutect2, varscan2
- SEZ6L | c.1652C>A p.A551E | Missense Mutation (SNP) | VAF 102/284 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.017); catalogued as rs201841723; called by muse, mutect2, varscan2
- SFXN4 | c.536G>T p.G179V | Missense Mutation (SNP) | VAF 18/106 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs748633967; called by muse, mutect2, varscan2
- SHOX | c.577G>A p.A193T | Missense Mutation (SNP) | VAF 143/505 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as rs376330042, COSV100479115; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SHROOM3 | c.2627G>T p.R876L | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT tolerated (0.51); PolyPhen benign (0.012); catalogued as COSV56041276; called by muse, mutect2, varscan2
- SI | c.1306G>T p.A436S | Missense Mutation (SNP) | VAF 124/381 reads (33%) | SIFT tolerated (0.66); PolyPhen benign (0.009); catalogued as COSV52284259; called by muse, mutect2, varscan2
- SI | c.155G>T p.R52L | Missense Mutation (SNP) | VAF 87/273 reads (32%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV52302866; called by muse, mutect2, varscan2
- SIGLEC14 | c.844G>A p.A282T | Missense Mutation (SNP) | VAF 74/135 reads (55%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs764208232; called by muse, mutect2, varscan2
- SIGLEC9 | c.509G>T p.C170F | Missense Mutation (SNP) | VAF 104/395 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51583389; called by muse, mutect2, varscan2
- SIM1 | c.918G>T p.W306C | Missense Mutation (SNP) | VAF 132/372 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99492175; called by muse, mutect2, varscan2
- SIPA1L2 | c.2491A>G p.I831V | Missense Mutation (SNP) | VAF 171/470 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs751223235; called by muse, mutect2, varscan2
- SLC12A3 | c.2029G>T p.V677L | Missense Mutation (SNP) | VAF 18/244 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.409); catalogued as CM021333, CM076523, COSV52636010; called by muse, mutect2
- SLC15A3 | c.434C>T p.S145L | Missense Mutation (SNP) | VAF 62/156 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.231); catalogued as rs866015673; called by muse, varscan2
- SLC16A4 | c.137T>C p.V46A | Missense Mutation (SNP) | VAF 23/106 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs755710528; called by muse, mutect2, varscan2
- SLC16A7 | c.211G>T p.A71S | Missense Mutation (SNP) | VAF 68/174 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.426); catalogued as COSV53898155; called by muse, mutect2
- SLC17A8 | c.1405G>T p.G469C | Missense Mutation (SNP) | VAF 291/644 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs747411001, COSV60126852; called by muse, mutect2, varscan2
- SLC18A3 | c.295G>T p.A99S | Missense Mutation (SNP) | VAF 78/234 reads (33%) | SIFT tolerated (0.74); PolyPhen benign (0.003); catalogued as COSV100340776, COSV60325925; called by muse, mutect2, varscan2
- SLC22A25 | c.937G>T p.D313Y | Missense Mutation (SNP) | VAF 110/360 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV60594467; called by muse, mutect2, varscan2
- SLC23A1 | c.1021G>A p.A341T | Missense Mutation (SNP) | VAF 24/258 reads (9%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.671); catalogued as rs141189553; called by muse, mutect2
- SLC24A2 | c.274G>T p.D92Y | Missense Mutation (SNP) | VAF 120/322 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs1437735116; called by muse, mutect2, varscan2
- SLC26A8 | c.2638C>T p.R880W | Missense Mutation (SNP) | VAF 64/467 reads (14%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as rs1158010434, COSV62888136; called by muse, mutect2, varscan2
- SLC27A6 | c.891G>T p.W297C | Missense Mutation (SNP) | VAF 93/317 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52486931; called by muse, mutect2, varscan2
- SLC2A12 | c.593A>T p.Y198F | Missense Mutation (SNP) | VAF 159/377 reads (42%) | SIFT tolerated (0.16); PolyPhen benign (0.276); catalogued as COSV99259826; called by muse, mutect2, varscan2
- SLC2A4RG | c.646G>A p.A216T | Missense Mutation (SNP) | VAF 14/424 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.069); catalogued as rs1367229118; called by muse, mutect2
- SLC2A7 | c.1116G>A p.Q372= | Splice Region (SNP) | VAF 30/187 reads (16%) | catalogued as rs1299878624; called by muse, varscan2
- SLC37A1 | c.1126G>T p.G376* | Nonsense Mutation (SNP) | VAF 29/232 reads (13%) | catalogued as rs757935332; called by muse, mutect2, varscan2
- SLC39A12 | c.919G>T p.D307Y | Missense Mutation (SNP) | VAF 42/84 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.58); catalogued as COSV66196482; called by muse, mutect2, varscan2
- SLC39A12 | c.1747C>A p.P583T (on ENST00000377369 / NM_001145195.2; = p.P546T on NM_152725.3) | Missense Mutation (SNP) | VAF 21/339 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66201248; called by muse, mutect2
- SLC44A5 | c.520C>A p.P174T | Missense Mutation (SNP) | VAF 85/360 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV63765317; called by muse, mutect2, varscan2
- SLC4A1 | c.2189G>T p.R730L | Missense Mutation (SNP) | VAF 186/389 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.7); catalogued as rs746691107, COSV52259275; called by muse, mutect2, varscan2
- SLC6A5 | c.194C>T p.A65V | Missense Mutation (SNP) | VAF 77/196 reads (39%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.003); catalogued as rs768245472, COSV54227272; called by muse, mutect2, varscan2
- SLC7A2 | c.692G>T p.S231I (on ENST00000494857 / NM_001370338.1; = p.S271I on NM_003046.6) | Missense Mutation (SNP) | VAF 72/158 reads (46%) | SIFT tolerated (0.17); PolyPhen benign (0.009); catalogued as COSV99134240; called by muse, mutect2, varscan2
- SLC7A5 | c.208G>C p.V70L | Missense Mutation (SNP) | VAF 86/477 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.172); catalogued as rs778474124; called by muse, mutect2, varscan2
- SLFN12 | c.1482G>T p.M494I | Missense Mutation (SNP) | VAF 175/456 reads (38%) | SIFT tolerated (0.71); PolyPhen benign (0.003); catalogued as rs1459085908; called by muse, mutect2, varscan2
- SLFN13 | c.25G>T p.G9C | Missense Mutation (SNP) | VAF 58/97 reads (60%) | SIFT tolerated (0.06); PolyPhen benign (0.271); catalogued as COSV99540234; called by muse, mutect2, varscan2
- SMC3 | c.1120G>C p.D374H | Missense Mutation (SNP) | VAF 71/572 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.085); catalogued as COSV62418817; called by muse, mutect2, varscan2
- SMG5 | c.761G>T p.R254L | Missense Mutation (SNP) | VAF 160/385 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.371); catalogued as COSV62434597; called by muse, mutect2, varscan2
- SOWAHD | c.79C>T p.P27S | Missense Mutation (SNP) | VAF 56/152 reads (37%) | SIFT tolerated (0.45); PolyPhen benign (0.272); catalogued as rs1179660326; called by muse, mutect2, varscan2
- SP140 | c.314C>T p.T105I | Missense Mutation (SNP) | VAF 25/225 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.708); catalogued as rs746076516, COSV59450152; called by muse, mutect2, varscan2
- SPANXB1 | c.235C>T p.R79* | Nonsense Mutation (SNP) | VAF 111/2516 reads (4%) | catalogued as rs1218668228; called by muse, mutect2
- SPANXN2 | c.142G>T p.E48* | Nonsense Mutation (SNP) | VAF 44/178 reads (25%) | catalogued as rs782764510; called by muse, varscan2
- SPANXN3 | c.82C>A p.Q28K | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.968); catalogued as COSV65140850; called by muse, mutect2
- SPATA31A7 | c.251G>A p.G84D | Missense Mutation (SNP) | VAF 34/741 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.059); catalogued as rs1359109044; called by muse, mutect2
- SPEG | c.5299G>A p.E1767K | Missense Mutation (SNP) | VAF 60/196 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs765617604, COSV56676198; called by muse, mutect2, varscan2
- SPOCK1 | c.668G>T p.R223I | Missense Mutation (SNP) | VAF 57/169 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.776); catalogued as COSV56444670; called by muse, mutect2, varscan2
- SPON1 | c.592G>C p.D198H | Missense Mutation (SNP) | VAF 77/235 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.6); catalogued as rs12271588; called by muse, mutect2, varscan2
- SPRY2 | c.873C>A p.C291* | Nonsense Mutation (SNP) | VAF 168/451 reads (37%) | catalogued as COSV65701746; called by muse, mutect2, varscan2
- SPTA1 | c.76G>T p.E26* | Nonsense Mutation (SNP) | VAF 35/354 reads (10%) | catalogued as COSV100935504, COSV63757453; called by muse, mutect2, varscan2
- SPTLC2 | c.197C>T p.T66I | Missense Mutation (SNP) | VAF 50/800 reads (6%) | SIFT tolerated (0.2); PolyPhen benign (0.04); catalogued as COSV53641456; called by muse, mutect2
- SRRM4 | c.1439G>C p.R480P | Missense Mutation (SNP) | VAF 139/266 reads (52%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.505); catalogued as COSV57421278; called by muse, mutect2, varscan2
- SSC4D | c.319G>A p.V107M | Missense Mutation (SNP) | VAF 28/148 reads (19%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.624); catalogued as rs200166313; called by muse, mutect2, varscan2
- STAP1 | c.183G>C p.K61N | Missense Mutation (SNP) | VAF 64/182 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.149); catalogued as COSV55327541; called by muse, mutect2, varscan2
- STK10 | c.1852C>T p.R618C | Missense Mutation (SNP) | VAF 49/101 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs757807481, COSV51575397; called by muse, mutect2, varscan2
- STOX2 | c.2164T>C p.S722P | Missense Mutation (SNP) | VAF 91/172 reads (53%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as rs1196988892; called by muse, mutect2, varscan2
- STPG1 | c.179C>T p.P60L | Missense Mutation (SNP) | VAF 17/154 reads (11%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV50222361; called by muse, mutect2
- STRN4 | c.1255G>T p.D419Y | Missense Mutation (SNP) | VAF 30/110 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.62); catalogued as COSV54421601; called by muse, varscan2
- STYXL2 | c.1027G>T p.D343Y | Missense Mutation (SNP) | VAF 6/9 reads (67%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV54801809; called by muse, mutect2, varscan2
- SULT6B1 | c.286G>A p.E96K (on ENST00000535679 / NM_001367551.1; = p.E58K on NM_001032377.2) | Missense Mutation (SNP) | VAF 11/118 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs768365631; called by muse, mutect2
- SUPT5H | c.459G>T p.T153= | Splice Region (SNP) | VAF 42/239 reads (18%) | catalogued as COSV63240468; called by muse, mutect2, varscan2
- SUPT5H | c.2590G>C p.D864H | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV63240630; called by muse, mutect2, varscan2
- SUPT7L | c.323C>T p.S108L | Missense Mutation (SNP) | VAF 81/471 reads (17%) | SIFT tolerated (0.35); PolyPhen benign (0.039); catalogued as rs191619402; called by muse, mutect2, varscan2
- SV2A | c.695G>C p.R232T | Missense Mutation (SNP) | VAF 50/354 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs200377292; called by muse, mutect2, varscan2
- SYNE1 | c.21928C>G p.L7310V (on ENST00000367255 / NM_182961.4; = p.L7239V on NM_033071.3) | Missense Mutation (SNP) | VAF 81/630 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99586110; called by muse, mutect2, varscan2
- SYT4 | c.44C>A p.P15H | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54899464; called by muse, mutect2, varscan2
- TBC1D3F | c.1459G>T p.D487Y | Missense Mutation (SNP) | VAF 327/592 reads (55%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs777161263; called by muse, mutect2, varscan2
- TBX4 | c.352G>T p.D118Y | Missense Mutation (SNP) | VAF 222/465 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1206534268; called by muse, mutect2, varscan2
- TBX6 | c.1255C>G p.L419V | Missense Mutation (SNP) | VAF 61/407 reads (15%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.014); catalogued as rs1490709379; called by muse, mutect2, varscan2
- TDG | c.774G>T p.K258N | Missense Mutation (SNP) | VAF 23/115 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.242); catalogued as COSV57165966; called by muse, mutect2, varscan2
- TECRL | c.262G>T p.V88F | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.058); catalogued as COSV67089166; called by muse, mutect2, varscan2
- TEK | c.2396G>T p.G799V | Missense Mutation (SNP) | VAF 198/528 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs764309451; called by muse, mutect2, varscan2
- TEKT1 | c.493C>A p.R165S | Missense Mutation (SNP) | VAF 219/466 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100106519; called by muse, mutect2, varscan2
- TEKT4 | c.325A>C p.M109L | Missense Mutation (SNP) | VAF 273/487 reads (56%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV54623463; called by muse, mutect2, varscan2
- TENM1 | c.4045C>A p.Q1349K | Missense Mutation (SNP) | VAF 47/205 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.218); catalogued as rs1046691886, COSV64440824; called by muse, mutect2, varscan2
- TINAG | c.680G>A p.W227* | Nonsense Mutation (SNP) | VAF 32/211 reads (15%) | catalogued as rs1211659428; called by muse, mutect2, varscan2
- TKTL2 | c.1220G>T p.G407V | Missense Mutation (SNP) | VAF 266/600 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.958); catalogued as rs867327952; called by muse, mutect2, varscan2
- TLK1 | c.1272G>C p.L424F | Missense Mutation (SNP) | VAF 64/241 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62628722; called by muse, mutect2, varscan2
- TLR10 | c.2257G>T p.A753S | Missense Mutation (SNP) | VAF 52/146 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.156); catalogued as rs1560441029; called by muse, mutect2, varscan2
- TMC3 | c.3149G>A p.S1050N | Missense Mutation (SNP) | VAF 26/320 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.638); catalogued as rs370751216; called by muse, mutect2
- TMEM132C | c.668G>T p.G223V | Missense Mutation (SNP) | VAF 44/93 reads (47%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as rs1352878747, COSV70659918; called by muse, mutect2, varscan2
- TMEM132D | c.2313G>T p.M771I | Missense Mutation (SNP) | VAF 143/309 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.31); catalogued as rs577207277, COSV67162991; called by muse, mutect2, varscan2
- TMEM132D | c.788C>T p.P263L | Missense Mutation (SNP) | VAF 159/478 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.066); catalogued as rs867202541; called by muse, mutect2, varscan2
- TMTC1 | c.1099T>A p.L367M (on ENST00000539277 / NM_001193451.2; = p.L259M on NM_175861.3) | Missense Mutation (SNP) | VAF 63/183 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.442); catalogued as rs752115639; called by muse, mutect2, varscan2
- TNN | c.481A>T p.R161W | Missense Mutation (SNP) | VAF 35/294 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53426195; called by muse, mutect2, varscan2
- TNN | c.2833C>A p.P945T | Missense Mutation (SNP) | VAF 61/572 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99513201; called by muse, varscan2
- TNR | c.2507C>G p.P836R | Missense Mutation (SNP) | VAF 38/444 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99691886; called by muse, mutect2
- TOPBP1 | c.2639G>T p.R880L | Missense Mutation (SNP) | VAF 143/402 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.297); catalogued as rs765802731; called by muse, varscan2
- TPP1 | c.797G>T p.R266L | Missense Mutation (SNP) | VAF 183/447 reads (41%) | SIFT tolerated (0.32); PolyPhen benign (0.005); catalogued as CM050197, COSV54993808; called by muse, mutect2, varscan2
- TPPP2 | c.28C>G p.H10D | Missense Mutation (SNP) | VAF 52/209 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.038); catalogued as COSV100069420; called by muse, mutect2, varscan2
- TRIM15 | c.770C>A p.S257Y | Missense Mutation (SNP) | VAF 20/200 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.797); catalogued as COSV100938929, COSV64989180; called by muse, mutect2
- TRIM40 | c.134C>T p.A45V | Missense Mutation (SNP) | VAF 62/768 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); catalogued as rs758656723; called by muse, mutect2
- TRIM58 | c.157G>A p.G53S | Missense Mutation (SNP) | VAF 76/180 reads (42%) | SIFT tolerated (0.19); PolyPhen benign (0.107); catalogued as rs923257851; called by muse, varscan2
- TRIT1 | c.637G>T p.G213C | Missense Mutation (SNP) | VAF 63/495 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as rs758324281; called by muse, mutect2, varscan2
- TRO | c.1293G>T p.W431C | Missense Mutation (SNP) | VAF 39/129 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.86); catalogued as COSV51505273; called by muse, mutect2, varscan2
- TSGA10 | c.677A>G p.Y226C | Missense Mutation (SNP) | VAF 70/157 reads (45%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.896); catalogued as rs377151625; called by muse, mutect2, varscan2
- TSHZ2 | c.1956G>T p.K652N | Missense Mutation (SNP) | VAF 50/166 reads (30%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV100296701, COSV61591449; called by muse, mutect2, varscan2
- TSPAN17 | c.245G>T p.C82F | Missense Mutation (SNP) | VAF 169/331 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as COSV53782264; called by muse, mutect2, varscan2
- TSSK2 | c.388C>G p.L130V | Missense Mutation (SNP) | VAF 75/283 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.102); catalogued as COSV99350830; called by muse, mutect2, varscan2
- TTN | c.64963del p.L21655Sfs*34 (on ENST00000591111; = p.L14231Sfs*34 on NM_003319.4) | Frame Shift Del (DEL) | VAF 17/82 reads (21%) | catalogued as COSV59937582, COSV60246638; called by mutect2, pindel, varscan2
- TTN | c.13682G>A p.C4561Y (on ENST00000591111; = p.C3634Y on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 67/216 reads (31%) | PolyPhen possibly damaging (0.706); catalogued as rs546830236; called by muse, mutect2, varscan2
- TTN | c.7199G>T p.R2400M (on ENST00000591111; = p.R2354M on NM_003319.4) | Missense Mutation (SNP) | VAF 152/428 reads (36%) | PolyPhen probably damaging (0.998); catalogued as COSV60310718; called by muse, mutect2, varscan2
- TTN | c.6007C>A p.R2003S (on ENST00000591111; = p.R1957S on NM_003319.4) | Missense Mutation (SNP) | VAF 122/279 reads (44%) | PolyPhen probably damaging (0.998); catalogued as COSV59900446; called by muse, mutect2, varscan2
- TUSC3 | c.309G>T p.R103S | Missense Mutation (SNP) | VAF 168/457 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.088); catalogued as COSV65881139; called by muse, mutect2, varscan2
- UCK1 | c.28G>C p.E10Q | Missense Mutation (SNP) | VAF 63/143 reads (44%) | SIFT tolerated (0.35); PolyPhen benign (0.057); catalogued as rs1318420787; called by muse, mutect2, varscan2
- UGT1A1 | c.23G>T p.G8V | Missense Mutation (SNP) | VAF 116/256 reads (45%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0.007); catalogued as rs768521253; called by muse, varscan2
- UGT3A1 | c.496C>A p.L166I | Missense Mutation (SNP) | VAF 32/205 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.034); catalogued as COSV57101427; called by muse, mutect2, varscan2
- UNC93A | c.314C>A p.A105D | Missense Mutation (SNP) | VAF 122/367 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs569646477; called by muse, mutect2, varscan2
- USF3 | c.202G>T p.E68* | Nonsense Mutation (SNP) | VAF 18/311 reads (6%) | catalogued as COSV100325512; called by muse, mutect2
- USH2A | c.11716C>T p.P3906S | Missense Mutation (SNP) | VAF 153/428 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.255); catalogued as rs772660259; called by muse, mutect2, varscan2
- USH2A | c.7044G>T p.R2348S | Missense Mutation (SNP) | VAF 184/488 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.039); catalogued as rs1376739699, COSV56351170; called by muse, mutect2, varscan2
- USH2A | c.5842C>T p.R1948C | Missense Mutation (SNP) | VAF 44/784 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs145647517; called by muse, mutect2
- USP19 | c.1700C>T p.P567L | Missense Mutation (SNP) | VAF 31/250 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1261527898, COSV60044916; called by muse, mutect2, varscan2
- USP29 | c.1423C>A p.L475I | Missense Mutation (SNP) | VAF 26/173 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.928); catalogued as rs149474650; called by muse, mutect2, varscan2
- UTP14C | c.219C>A p.F73L | Missense Mutation (SNP) | VAF 317/809 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1026544488; called by muse, mutect2, varscan2
- VCAN | c.4007G>A p.R1336Q | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.207); catalogued as rs372244245, COSV54098984; called by muse, mutect2, varscan2
- VCP | c.186G>T p.K62N | Missense Mutation (SNP) | VAF 271/553 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV100734385; called by muse, mutect2, varscan2
- VPS13C | c.9559A>G p.I3187V (on ENST00000644861 / NM_020821.3; = p.I3144V on NM_017684.5) | Missense Mutation (SNP) | VAF 40/137 reads (29%) | SIFT tolerated (0.29); PolyPhen benign (0.298); catalogued as rs1386999695; called by muse, mutect2, varscan2
- VSTM1 | c.601C>A p.P201T | Missense Mutation (SNP) | VAF 40/124 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.396); catalogued as rs1161238790, COSV58074749; called by muse, mutect2, varscan2
- WDR62 | c.59C>T p.S20F | Missense Mutation (SNP) | VAF 94/367 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.548); catalogued as rs1315314870; called by muse, mutect2, varscan2
- YIPF4 | c.364_366del p.V122del | In Frame Del (DEL) | VAF 33/192 reads (17%) | catalogued as rs750061732; called by pindel, varscan2
- ZC3H4 | c.3609G>T p.K1203N | Missense Mutation (SNP) | VAF 62/184 reads (34%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.994); catalogued as COSV99451636, COSV99452941; called by muse, mutect2, varscan2
- ZC3H6 | c.3050G>T p.G1017V | Missense Mutation (SNP) | VAF 112/226 reads (50%) | SIFT tolerated (0.1); PolyPhen benign (0.05); catalogued as rs764712806; called by muse, mutect2, varscan2
- ZC3HAV1L | c.167C>T p.T56M | Missense Mutation (SNP) | VAF 152/306 reads (50%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.001); catalogued as rs779584170; called by muse, mutect2, varscan2
- ZFHX4 | c.172A>T p.S58C | Missense Mutation (SNP) | VAF 91/311 reads (29%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.794); catalogued as COSV50976356; called by muse, mutect2, varscan2
- ZFHX4 | c.586C>A p.H196N | Missense Mutation (SNP) | VAF 103/340 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV51495604; called by mutect2, varscan2
- ZFHX4 | c.4073C>A p.S1358* | Nonsense Mutation (SNP) | VAF 102/429 reads (24%) | catalogued as COSV99255602; called by muse, mutect2, varscan2
- ZIC1 | c.431C>A p.P144H | Missense Mutation (SNP) | VAF 30/266 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV51551798; called by muse, mutect2, varscan2
- ZNF257 | c.1158C>A p.H386Q | Missense Mutation (SNP) | VAF 94/265 reads (35%) | SIFT tolerated (0.36); PolyPhen benign (0.01); catalogued as rs375438382; called by muse, mutect2, varscan2
- ZNF334 | c.1715A>G p.Y572C | Missense Mutation (SNP) | VAF 46/318 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.86); catalogued as rs769146818, COSV61619033; called by muse, mutect2, varscan2
- ZNF385B | c.299-1G>A p.X100_splice | Splice Site (SNP) | VAF 119/256 reads (46%) | catalogued as rs1429214854; called by muse, mutect2, varscan2
- ZNF420 | c.496C>T p.P166S | Missense Mutation (SNP) | VAF 31/213 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.497); catalogued as COSV58496966; called by muse, mutect2, varscan2
- ZNF479 | c.1138C>A p.P380T | Missense Mutation (SNP) | VAF 30/342 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV58637540; called by muse, mutect2
- ZNF493 | c.296G>C p.R99T | Missense Mutation (SNP) | VAF 10/164 reads (6%) | SIFT tolerated (0.44); PolyPhen benign (0.082); catalogued as COSV62750174; called by muse, mutect2
- ZNF567 | c.92A>G p.Y31C | Missense Mutation (SNP) | VAF 153/470 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1476211961, COSV62445996; called by muse, mutect2, varscan2
- ZNF679 | c.106G>A p.A36T | Missense Mutation (SNP) | VAF 88/365 reads (24%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as rs538401113, COSV55381214; called by muse, mutect2, varscan2
- ZNF679 | c.409C>A p.Q137K | Missense Mutation (SNP) | VAF 69/505 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.01); catalogued as rs758602962; called by muse, mutect2, varscan2
- ZNF804B | c.355G>A p.A119T | Missense Mutation (SNP) | VAF 49/488 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60826123; called by muse, mutect2, varscan2
- ZNF880 | c.700C>T p.H234Y | Missense Mutation (SNP) | VAF 54/296 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs759826917, COSV69905861; called by muse, mutect2, varscan2
- ZNF98 | c.514C>A p.H172N | Missense Mutation (SNP) | VAF 32/97 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.092); catalogued as COSV63339672; called by muse, mutect2, varscan2
- ZSCAN4 | c.167C>T p.S56L | Missense Mutation (SNP) | VAF 39/260 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.048); catalogued as COSV58999394; called by muse, mutect2, varscan2
- ZXDA | c.652G>A p.G218S | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs1297395072; called by muse, mutect2, varscan2
- A1CF | c.601C>A p.P201T | Missense Mutation (SNP) | VAF 29/82 reads (35%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.494); called by muse, mutect2, varscan2
- A2M | c.3760A>T p.T1254S | Missense Mutation (SNP) | VAF 49/211 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- A4GALT | c.818G>C p.C273S | Missense Mutation (SNP) | VAF 105/281 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- A4GNT | c.64C>A p.Q22K | Missense Mutation (SNP) | VAF 38/89 reads (43%) | SIFT tolerated (0.91); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ABCA12 | c.2308A>T p.K770* (on ENST00000272895 / NM_173076.3; = p.K452* on NM_015657.3) | Nonsense Mutation (SNP) | VAF 10/290 reads (3%) | called by muse, mutect2
- ABCA2 | c.422A>T p.D141V (on ENST00000614293; = p.D111V on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 72/172 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- ABCB5 | c.2066G>A p.W689* (on ENST00000404938 / NM_001163941.2; = p.W244* on NM_178559.6) | Nonsense Mutation (SNP) | VAF 10/177 reads (6%) | called by muse, mutect2
- ABCF1 | c.1981G>T p.G661C (on ENST00000326195 / NM_001025091.2; = p.G623C on NM_001090.3) | Missense Mutation (SNP) | VAF 34/496 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ABCG1 | c.999C>A p.Y333* | Nonsense Mutation (SNP) | VAF 10/65 reads (15%) | called by muse, mutect2, varscan2
- ABI2 | c.417A>T p.K139N | Missense Mutation (SNP) | VAF 17/115 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- ABLIM1 | c.1857G>C p.L619F | Missense Mutation (SNP) | VAF 79/177 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- AC024940.1 | n.2466+2T>C | Splice Site (SNP) | VAF 168/539 reads (31%) | called by muse, mutect2, varscan2
- AC069544.2 | c.409G>T p.G137C | Missense Mutation (SNP) | VAF 295/556 reads (53%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.57); called by muse, mutect2, varscan2
- AC132807.2 | n.132A>C | Splice Region (SNP) | VAF 30/658 reads (5%) | called by muse, mutect2
- ACACA | c.6248G>T p.W2083L | Missense Mutation (SNP) | VAF 261/586 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ACAN | c.476C>A p.A159D | Missense Mutation (SNP) | VAF 59/219 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ACE2 | c.1159G>T p.A387S | Missense Mutation (SNP) | VAF 84/343 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ACSBG1 | c.1322G>A p.G441E | Missense Mutation (SNP) | VAF 109/303 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ACTRT1 | c.175C>A p.Q59K | Missense Mutation (SNP) | VAF 37/133 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- ACY3 | c.328G>C p.D110H | Missense Mutation (SNP) | VAF 21/271 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- ADAM2 | c.198A>T p.L66F | Missense Mutation (SNP) | VAF 56/140 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ADAM30 | c.1253C>A p.T418K | Missense Mutation (SNP) | VAF 24/244 reads (10%) | SIFT tolerated (0.97); PolyPhen benign (0.003); called by muse, mutect2
- ADAMTS12 | c.2747C>G p.S916C | Missense Mutation (SNP) | VAF 104/357 reads (29%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- ADAMTS14 | c.2528T>G p.L843R | Missense Mutation (SNP) | VAF 32/154 reads (21%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.735); called by muse, mutect2, varscan2
- ADAMTS20 | c.1322G>T p.W441L | Missense Mutation (SNP) | VAF 127/358 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- ADARB1 | c.1643G>T p.G548V (on ENST00000360697 / NM_001346687.2; = p.G508V on NM_001112.4) | Missense Mutation (SNP) | VAF 38/215 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- ADARB2 | c.1472G>T p.G491V | Missense Mutation (SNP) | VAF 13/211 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ADCY1 | c.773A>T p.D258V | Missense Mutation (SNP) | VAF 55/204 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.007); called by muse, mutect2
- ADGRD2 | c.1180C>A p.L394I | Missense Mutation (SNP) | VAF 80/177 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ADGRD2 | c.1420G>T p.V474L | Missense Mutation (SNP) | VAF 90/240 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- ADGRF2 | c.1397_1400del p.S466Lfs*4 (on ENST00000296862 / NM_001368115.2; = p.S398Lfs*4 on NM_153839.7) | Frame Shift Del (DEL) | VAF 78/306 reads (25%) | called by mutect2, pindel, varscan2
- ADGRG2 | c.3014C>A p.T1005N (on ENST00000379869 / NM_001079858.3; = p.T1002N on NM_005756.4) | Missense Mutation (SNP) | VAF 29/149 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADGRG4 | c.5450C>A p.P1817H | Missense Mutation (SNP) | VAF 25/153 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.67); called by muse, mutect2, varscan2
- ADNP | c.1969G>A p.E657K | Missense Mutation (SNP) | VAF 167/499 reads (33%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.775); called by muse, mutect2, varscan2
- AGBL1 | c.1424G>A p.C475Y | Missense Mutation (SNP) | VAF 35/98 reads (36%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.787); called by muse, mutect2, varscan2
- AHCTF1 | c.6401C>G p.T2134S (on ENST00000366508; = p.T2108S on NM_015446.5) | Missense Mutation (SNP) | VAF 133/463 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.592); called by muse, mutect2, varscan2
- AHCTF1 | c.5089G>T p.E1697* (on ENST00000366508; = p.E1671* on NM_015446.5) | Nonsense Mutation (SNP) | VAF 26/447 reads (6%) | called by muse, mutect2
- AHDC1 | c.1187G>T p.R396L | Missense Mutation (SNP) | VAF 56/173 reads (32%) | SIFT tolerated (0.26); PolyPhen benign (0.35); called by muse, mutect2, varscan2
- AHNAK2 | c.16396C>A p.H5466N | Missense Mutation (SNP) | VAF 72/345 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.384); called by muse, mutect2, varscan2
- AIRE | c.1019G>T p.C340F | Missense Mutation (SNP) | VAF 126/380 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- AKAP12 | c.748G>T p.A250S | Missense Mutation (SNP) | VAF 168/314 reads (54%) | SIFT tolerated (0.36); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- AKAP6 | c.6811G>T p.A2271S | Missense Mutation (SNP) | VAF 79/434 reads (18%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- AKAP9 | c.2311G>T p.A771S | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated (0.72); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- AL121899.2 | c.341C>G p.T114S | Missense Mutation (SNP) | VAF 180/478 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- AL121899.2 | c.1285T>C p.W429R | Missense Mutation (SNP) | VAF 257/627 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ALKBH8 | c.632G>T p.W211L | Missense Mutation (SNP) | VAF 75/223 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ALMS1 | c.10del p.E4Rfs*37 | Frame Shift Del (DEL) | VAF 40/256 reads (16%) | called by pindel, varscan2
- ALMS1 | c.2691G>T p.K897N | Missense Mutation (SNP) | VAF 111/229 reads (48%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.73); called by muse, mutect2, varscan2
- ALPK3 | c.44G>T p.G15V | Missense Mutation (SNP) | VAF 59/133 reads (44%) | SIFT tolerated (0.32); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ALS2CL | c.656G>T p.G219V | Missense Mutation (SNP) | VAF 50/89 reads (56%) | SIFT tolerated (0.07); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- AMD1 | c.119G>T p.W40L | Missense Mutation (SNP) | VAF 46/120 reads (38%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.554); called by muse, mutect2, varscan2
- AMER2 | c.1270G>A p.E424K | Missense Mutation (SNP) | VAF 114/198 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- ANK1 | c.4130G>T p.R1377M | Missense Mutation (SNP) | VAF 245/959 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- ANK3 | c.6382A>T p.S2128C | Missense Mutation (SNP) | VAF 74/206 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ANK3 | c.4481A>T p.Y1494F | Missense Mutation (SNP) | VAF 68/193 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- ANKRA2 | c.920T>A p.L307Q | Missense Mutation (SNP) | VAF 45/158 reads (28%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- ANKRD26 | c.2419A>T p.T807S | Missense Mutation (SNP) | VAF 95/228 reads (42%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- ANKRD27 | c.604G>T p.E202* | Nonsense Mutation (SNP) | VAF 149/523 reads (28%) | called by muse, mutect2, varscan2
- ANKRD30A | c.337-1G>T p.X113_splice (on ENST00000611781; = p.X57_splice on NM_052997.2) | Splice Site (SNP) | VAF 72/434 reads (17%) | called by muse, varscan2
- ANKRD36B | c.1182G>T p.Q394H | Missense Mutation (SNP) | VAF 86/499 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- ANKRD36C | c.4292G>T p.C1431F | Missense Mutation (SNP) | VAF 360/771 reads (47%) | SIFT tolerated (0.1); PolyPhen benign (0.318); called by muse, mutect2, varscan2
- ANO1 | c.1904G>T p.R635L | Missense Mutation (SNP) | VAF 78/201 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- APOA2 | c.298C>A p.Q100K | Missense Mutation (SNP) | VAF 77/173 reads (45%) | SIFT tolerated (0.51); PolyPhen benign (0); called by muse, mutect2, varscan2
- APOB | c.1353C>T p.N451= | Splice Region (SNP) | VAF 186/367 reads (51%) | called by muse, mutect2, varscan2
- APOC1 | c.244G>C p.D82H | Missense Mutation (SNP) | VAF 87/251 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- APP | c.782C>T p.P261L | Missense Mutation (SNP) | VAF 158/549 reads (29%) | SIFT tolerated (0.32); PolyPhen benign (0.007); called by muse, varscan2
- AQP10 | c.74T>A p.L25Q | Missense Mutation (SNP) | VAF 32/388 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- ARHGAP15 | c.474G>T p.Q158H | Missense Mutation (SNP) | VAF 98/299 reads (33%) | SIFT tolerated (0.62); PolyPhen benign (0.395); called by muse, mutect2, varscan2
- ARHGAP26 | c.1293G>T p.K431N | Missense Mutation (SNP) | VAF 38/88 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- ARHGAP33 | c.94C>A p.P32T | Missense Mutation (SNP) | VAF 35/155 reads (23%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.23); called by muse, mutect2, varscan2
- ARHGAP33 | c.533G>T p.S178I | Missense Mutation (SNP) | VAF 67/189 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.452); called by muse, mutect2, varscan2
- ARHGEF19 | c.1690A>T p.M564L | Missense Mutation (SNP) | VAF 31/244 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- ARHGEF19 | c.1179C>G p.H393Q | Missense Mutation (SNP) | VAF 22/183 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.315); called by muse, mutect2, varscan2
- ARID1B | c.308A>T p.H103L | Missense Mutation (SNP) | VAF 210/496 reads (42%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.007); called by muse, varscan2
- ARID1B | c.6238G>T p.D2080Y | Missense Mutation (SNP) | VAF 38/392 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- ARMCX3 | c.868G>T p.G290C | Missense Mutation (SNP) | VAF 22/117 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- ARSG | c.828G>T p.M276I | Missense Mutation (SNP) | VAF 278/567 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.266); called by muse, mutect2, varscan2
- ASAH1 | c.267A>C p.L89= | Splice Region (SNP) | VAF 77/185 reads (42%) | called by muse, mutect2, varscan2
- ASB10 | c.202G>A p.G68S | Missense Mutation (SNP) | VAF 107/330 reads (32%) | SIFT tolerated (0.41); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ASB17 | c.113G>A p.W38* | Nonsense Mutation (SNP) | VAF 87/394 reads (22%) | called by muse, mutect2, varscan2
- ASB5 | c.868C>A p.P290T | Missense Mutation (SNP) | VAF 85/220 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ASMT | c.236G>T p.G79V | Missense Mutation (SNP) | VAF 108/298 reads (36%) | SIFT tolerated (0.17); PolyPhen benign (0.116); called by muse, mutect2, varscan2
- ASXL3 | c.1976C>A p.T659K | Missense Mutation (SNP) | VAF 45/179 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- ATAD3C | c.631_634del p.R211Kfs*3 | Frame Shift Del (DEL) | VAF 33/193 reads (17%) | called by mutect2, pindel, varscan2
- ATE1 | c.1029G>T p.Q343H | Missense Mutation (SNP) | VAF 131/254 reads (52%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- ATG2A | c.701T>A p.L234Q | Missense Mutation (SNP) | VAF 144/616 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.159); called by muse, varscan2
- ATG2B | c.478G>T p.V160L | Missense Mutation (SNP) | VAF 38/147 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); called by muse, mutect2
- ATP1A4 | c.1036G>T p.A346S | Missense Mutation (SNP) | VAF 27/214 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- ATP2B2 | c.1066G>T p.G356C (on ENST00000352432; = p.G322C on NM_001683.5) | Missense Mutation (SNP) | VAF 145/255 reads (57%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- B3GALT6 | c.598G>A p.E200K | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- BAHCC1 | c.4935_4951+2del | Frame Shift Del (DEL) | VAF 28/214 reads (13%) | called by mutect2, pindel
- BARD1 | c.806C>T p.S269F | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- BCAN | c.2641C>T p.H881Y | Missense Mutation (SNP) | VAF 138/334 reads (41%) | SIFT tolerated (0.36); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- BCAT2 | c.25-8C>T | Splice Region (SNP) | VAF 48/124 reads (39%) | called by muse, mutect2, varscan2
- BCOR | c.3383C>A p.P1128H | Missense Mutation (SNP) | VAF 107/489 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- BCOR | c.764C>A p.P255H | Missense Mutation (SNP) | VAF 27/137 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BDKRB2 | c.151G>C p.E51Q | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.372); called by muse, mutect2, varscan2
- BEND2 | c.370T>A p.C124S | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT tolerated, low confidence (0.83); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- BHLHE23 | c.137G>C p.G46A (on ENST00000370346; = p.G62A on NM_080606.4) | Missense Mutation (SNP) | VAF 39/108 reads (36%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- BIN1 | c.1399G>C p.G467R (on ENST00000316724 / NM_001320642.1; = p.G328R on NM_004305.4) | Missense Mutation (SNP) | VAF 62/443 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- BMP7 | c.1277G>T p.R426L | Missense Mutation (SNP) | VAF 123/706 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- BPIFC | c.595-2A>T p.X199_splice | Splice Site (SNP) | VAF 162/536 reads (30%) | called by muse, mutect2, varscan2
- BRAT1 | c.530G>A p.R177Q | Missense Mutation (SNP) | VAF 71/218 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- BRDT | c.853G>T p.A285S | Missense Mutation (SNP) | VAF 69/321 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- BRSK1 | c.221T>G p.V74G | Missense Mutation (SNP) | VAF 50/273 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- BRWD1 | c.878G>T p.G293V | Missense Mutation (SNP) | VAF 26/180 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- C16orf78 | c.160C>G p.P54A | Missense Mutation (SNP) | VAF 40/108 reads (37%) | SIFT tolerated (0.63); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- C19orf57 | c.1576G>T p.A526S | Missense Mutation (SNP) | VAF 89/212 reads (42%) | SIFT tolerated (0.54); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- C1QL3 | c.257C>A p.P86H | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.456); called by muse, mutect2, varscan2
- C1QTNF3 | c.98G>C p.G33A | Missense Mutation (SNP) | VAF 84/315 reads (27%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.981); called by muse, varscan2
- C1RL | c.519G>T p.E173D | Missense Mutation (SNP) | VAF 62/292 reads (21%) | SIFT tolerated (0.62); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- C1S | c.1891G>C p.D631H | Missense Mutation (SNP) | VAF 71/218 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- C21orf58 | c.445G>T p.E149* | Nonsense Mutation (SNP) | VAF 31/187 reads (17%) | called by muse, mutect2, varscan2
- C2CD3 | c.2999G>T p.G1000V | Missense Mutation (SNP) | VAF 60/256 reads (23%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.463); called by muse, mutect2, varscan2
- C5AR2 | c.376G>T p.A126S | Missense Mutation (SNP) | VAF 74/495 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- C6orf120 | c.226G>T p.A76S | Missense Mutation (SNP) | VAF 37/512 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- C7orf33 | c.269C>A p.T90N | Missense Mutation (SNP) | VAF 182/508 reads (36%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- C8orf74 | c.332G>T p.C111F | Missense Mutation (SNP) | VAF 160/366 reads (44%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.931); called by mutect2, varscan2
- CACNA1C | c.5467G>C p.D1823H | Missense Mutation (SNP) | VAF 21/109 reads (19%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.121); called by muse, mutect2, varscan2
- CACNA1G | c.6878A>T p.Q2293L | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.146); called by muse, mutect2, varscan2
- CACNA1H | c.1394G>C p.G465A | Missense Mutation (SNP) | VAF 184/557 reads (33%) | SIFT tolerated (0.67); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- CACNB4 | c.388G>A p.E130K | Missense Mutation (SNP) | VAF 135/344 reads (39%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- CADM3 | c.848C>A p.A283D (on ENST00000368125 / NM_001127173.3; = p.A317D on NM_021189.5) | Missense Mutation (SNP) | VAF 38/429 reads (9%) | SIFT tolerated (0.57); PolyPhen benign (0.027); called by muse, mutect2
- CAPN11 | c.570C>G p.D190E | Missense Mutation (SNP) | VAF 24/294 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2
- CARD8 | c.1091C>A p.P364Q (on ENST00000651546 / NM_001184900.3; = p.P314Q on NM_014959.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 74/263 reads (28%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- CARD8 | c.694G>T p.G232C (on ENST00000651546 / NM_001184900.3; = p.G182C on NM_014959.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 124/543 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CARD8 | c.122A>C p.K41T | Missense Mutation (SNP) | VAF 106/436 reads (24%) | SIFT tolerated, low confidence (0.84); PolyPhen benign (0); called by muse, mutect2, varscan2
- CASK | c.2146C>A p.H716N | Missense Mutation (SNP) | VAF 83/567 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- CATSPER3 | c.99G>A p.K33= | Splice Region (SNP) | VAF 159/484 reads (33%) | called by muse, mutect2, varscan2
- CBFA2T3 | c.1916C>A p.P639H | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.343); called by muse, mutect2, varscan2
- CBLB | c.1274C>T p.P425L | Missense Mutation (SNP) | VAF 98/839 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CBY1 | c.261G>C p.E87D | Missense Mutation (SNP) | VAF 118/461 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CCDC157 | c.868G>T p.V290L | Missense Mutation (SNP) | VAF 122/426 reads (29%) | SIFT tolerated (0.71); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CCDC168 | c.20566C>T p.P6856S | Missense Mutation (SNP) | VAF 73/220 reads (33%) | SIFT tolerated (0.27); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- CCDC168 | c.12179dup p.I4062Nfs*6 | Frame Shift Ins (INS) | VAF 100/295 reads (34%) | called by mutect2, pindel, varscan2
- CCDC168 | c.10803G>A p.M3601I | Missense Mutation (SNP) | VAF 34/93 reads (37%) | SIFT tolerated (0.35); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- CCDC168 | c.8633G>T p.R2878M | Missense Mutation (SNP) | VAF 86/184 reads (47%) | SIFT tolerated (0.12); PolyPhen benign (0.405); called by muse, mutect2, varscan2
- CCDC40 | c.1019A>T p.H340L | Missense Mutation (SNP) | VAF 101/615 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0); called by muse, mutect2, varscan2
- CCDC9B | c.663G>A p.W221* | Nonsense Mutation (SNP) | VAF 30/94 reads (32%) | called by muse, mutect2, varscan2
- CCN5 | c.136G>T p.V46L | Missense Mutation (SNP) | VAF 72/442 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.169); called by muse, mutect2, varscan2
- CCN6 | c.44C>T p.A15V | Missense Mutation (SNP) | VAF 198/502 reads (39%) | SIFT tolerated (0.36); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CCT7 | c.187G>T p.A63S | Missense Mutation (SNP) | VAF 91/229 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CD40 | c.418G>T p.D140Y | Missense Mutation (SNP) | VAF 108/699 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); called by muse, mutect2, varscan2
- CDC20B | c.523G>T p.V175F | Missense Mutation (SNP) | VAF 67/247 reads (27%) | SIFT tolerated (0.69); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CDH10 | c.1131T>A p.D377E | Missense Mutation (SNP) | VAF 36/583 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- CDH12 | c.626T>C p.F209S | Missense Mutation (SNP) | VAF 16/364 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CDH23 | c.3494C>A p.P1165H | Missense Mutation (SNP) | VAF 43/412 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- CDH26 | c.670A>T p.S224C | Missense Mutation (SNP) | VAF 114/291 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- CDH4 | c.1963C>A p.P655T | Missense Mutation (SNP) | VAF 175/367 reads (48%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CDHR2 | c.305C>A p.P102H | Missense Mutation (SNP) | VAF 70/168 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- CDHR4 | c.963G>T p.K321N | Missense Mutation (SNP) | VAF 147/359 reads (41%) | SIFT tolerated (0.25); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- CDK11A | c.2042C>T p.S681L (on ENST00000378633 / NM_001313896.2; = p.S678L on NM_024011.4) | Missense Mutation (SNP) | VAF 66/218 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- CDK13 | c.1341T>A p.S447R | Missense Mutation (SNP) | VAF 155/398 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- CDK17 | c.518G>A p.S173N | Missense Mutation (SNP) | VAF 27/393 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.947); called by muse, mutect2
- CEP170B | c.2927C>T p.T976I (on ENST00000453495; = p.T905I on NM_015005.3) | Missense Mutation (SNP) | VAF 47/168 reads (28%) | SIFT tolerated (0.28); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- CEP192 | c.5878A>C p.N1960H | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT tolerated (0.31); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CEP290 | c.5989G>A p.E1997K | Missense Mutation (SNP) | VAF 78/188 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CEP290 | c.5679G>C p.E1893D | Missense Mutation (SNP) | VAF 6/115 reads (5%) | SIFT tolerated (0.63); PolyPhen benign (0); called by muse, mutect2
- CEP57L1 | c.1146G>T p.K382N | Missense Mutation (SNP) | VAF 16/126 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.933); called by muse, mutect2
- CERS3 | c.853T>A p.Y285N | Missense Mutation (SNP) | VAF 11/146 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.462); called by muse, mutect2
- CFAP43 | c.1970C>T p.A657V | Missense Mutation (SNP) | VAF 53/185 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- CFAP46 | c.4780G>C p.D1594H | Missense Mutation (SNP) | VAF 56/89 reads (63%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.639); called by muse, mutect2, varscan2
- CFAP54 | c.4830G>T p.M1610I | Missense Mutation (SNP) | VAF 93/205 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CFH | c.2717G>T p.R906M | Missense Mutation (SNP) | VAF 142/345 reads (41%) | SIFT tolerated (0.2); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- CHAT | c.187G>A p.A63T | Missense Mutation (SNP) | VAF 39/90 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- CHD6 | c.4190G>T p.R1397L | Missense Mutation (SNP) | VAF 78/620 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- CHD8 | c.4276G>T p.D1426Y (on ENST00000646647 / NM_001170629.2; = p.D1147Y on NM_020920.4) | Missense Mutation (SNP) | VAF 117/493 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- CHGB | c.1227_1228insA p.G410Rfs*3 | Frame Shift Ins (INS) | VAF 103/354 reads (29%) | called by mutect2, pindel, varscan2
- CHN1 | c.826G>A p.A276T | Missense Mutation (SNP) | VAF 95/197 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.862); called by muse, mutect2, varscan2
- CHRNB2 | c.1102C>A p.R368S | Missense Mutation (SNP) | VAF 46/355 reads (13%) | SIFT tolerated (0.86); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- CIDEC | c.540del p.K181Sfs*4 | Frame Shift Del (DEL) | VAF 166/451 reads (37%) | called by mutect2, pindel, varscan2
- CLCN1 | c.1954G>T p.V652L | Missense Mutation (SNP) | VAF 37/100 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.869); called by muse, mutect2, varscan2
- CLDN17 | c.558C>A p.C186* | Nonsense Mutation (SNP) | VAF 184/539 reads (34%) | called by muse, mutect2, varscan2
- CLIP1 | c.1166A>T p.E389V | Missense Mutation (SNP) | VAF 161/326 reads (49%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- CLMN | c.13G>C p.E5Q | Missense Mutation (SNP) | VAF 79/309 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.376); called by muse, varscan2
- CNBD1 | c.391A>C p.T131P | Missense Mutation (SNP) | VAF 54/211 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- CNFN | c.326A>C p.K109T | Missense Mutation (SNP) | VAF 50/222 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.703); called by muse, varscan2
- CNTN2 | c.2771C>G p.S924* | Nonsense Mutation (SNP) | VAF 133/398 reads (33%) | called by muse, mutect2, varscan2
- CNTNAP4 | c.2569G>T p.G857W | Missense Mutation (SNP) | VAF 178/421 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CNTNAP4 | c.2570G>T p.G857V | Missense Mutation (SNP) | VAF 178/421 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CNTNAP5 | c.460T>A p.F154I | Missense Mutation (SNP) | VAF 49/412 reads (12%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CNTRL | c.255G>T p.E85D | Missense Mutation (SNP) | VAF 45/141 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- COG1 | c.690C>G p.F230L | Missense Mutation (SNP) | VAF 122/671 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.354); called by muse, mutect2, varscan2
- COG4 | c.1747G>A p.G583R | Missense Mutation (SNP) | VAF 257/531 reads (48%) | SIFT tolerated (0.4); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- COL11A1 | c.4988G>T p.W1663L | Missense Mutation (SNP) | VAF 39/583 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2
- COL11A1 | c.3364C>A p.P1122T | Missense Mutation (SNP) | VAF 64/626 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- COL15A1 | c.4006G>T p.D1336Y | Missense Mutation (SNP) | VAF 104/302 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- COL1A2 | c.1781C>A p.P594Q | Missense Mutation (SNP) | VAF 65/474 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.708); called by muse, mutect2, varscan2
- COL21A1 | c.1961C>G p.S654C | Missense Mutation (SNP) | VAF 44/341 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.19); called by muse, mutect2, varscan2
- COL24A1 | c.1238C>G p.T413R | Missense Mutation (SNP) | VAF 54/257 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- COL28A1 | c.732G>T p.K244N | Missense Mutation (SNP) | VAF 41/404 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- COL28A1 | c.286C>T p.L96F | Missense Mutation (SNP) | VAF 144/406 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- COL6A2 | c.1664G>C p.G555A | Missense Mutation (SNP) | VAF 98/391 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- COL6A2 | c.2723C>A p.T908K | Missense Mutation (SNP) | VAF 128/515 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- COL6A3 | c.3724C>T p.Q1242* | Nonsense Mutation (SNP) | VAF 117/266 reads (44%) | called by muse, mutect2, varscan2
- COL6A5 | c.2240C>A p.P747H | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COL6A5 | c.3416T>A p.V1139D | Missense Mutation (SNP) | VAF 162/461 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.676); called by muse, mutect2, varscan2
- CPA4 | c.1225C>A p.L409M | Missense Mutation (SNP) | VAF 37/270 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.648); called by muse, mutect2, varscan2
- CPS1 | c.76C>A p.H26N | Missense Mutation (SNP) | VAF 168/508 reads (33%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0); called by muse, mutect2, varscan2
- CPVL | c.775T>A p.L259M | Missense Mutation (SNP) | VAF 41/308 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.839); called by muse, mutect2, varscan2
- CPXM1 | c.1408C>A p.L470M | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT tolerated (0.23); PolyPhen benign (0.023); called by muse, mutect2
- CR2 | c.550G>T p.E184* | Nonsense Mutation (SNP) | VAF 244/698 reads (35%) | called by muse, mutect2, varscan2
- CRHR2 | c.484C>G p.R162G | Missense Mutation (SNP) | VAF 47/331 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- CRISPLD1 | c.996+1G>A p.X332_splice | Splice Site (SNP) | VAF 65/245 reads (27%) | called by muse, mutect2, varscan2
- CSF3R | c.764C>T p.P255L | Missense Mutation (SNP) | VAF 58/168 reads (35%) | SIFT tolerated (0.36); PolyPhen benign (0.264); called by muse, mutect2, varscan2
- CSMD1 | c.6278del p.P2093Hfs*7 (on ENST00000520002; = p.P2092Hfs*7 on NM_033225.6) | Frame Shift Del (DEL) | VAF 102/317 reads (32%) | called by mutect2, pindel, varscan2
- CSMD2 | c.1235C>A p.P412H | Missense Mutation (SNP) | VAF 109/348 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CSMD3 | c.4734G>T p.Q1578H (on ENST00000297405 / NM_001363185.1; = p.Q1474H on NM_052900.3) | Missense Mutation (SNP) | VAF 132/516 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- CSPP1 | c.1460G>T p.R487I (on ENST00000676605; = p.R446I on NM_024790.6) | Missense Mutation (SNP) | VAF 238/696 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- CTAGE1 | c.1526T>G p.L509W | Missense Mutation (SNP) | VAF 90/412 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CTNNA3 | c.910C>A p.L304I | Missense Mutation (SNP) | VAF 232/856 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- CXXC1 | c.1210A>T p.I404F | Missense Mutation (SNP) | VAF 51/157 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CYP2R1 | c.928G>T p.A310S | Missense Mutation (SNP) | VAF 50/116 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CYP2W1 | c.50T>A p.L17Q | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- CYP4A22 | c.838C>G p.L280V | Missense Mutation (SNP) | VAF 44/193 reads (23%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- CYTL1 | c.192C>A p.D64E | Missense Mutation (SNP) | VAF 61/157 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); called by muse, mutect2, varscan2
- DAB2 | c.569A>T p.E190V | Missense Mutation (SNP) | VAF 12/141 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.384); called by muse, mutect2
- DACH2 | c.868C>A p.Q290K | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.24); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- DACT2 | c.415C>A p.L139M | Missense Mutation (SNP) | VAF 160/368 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DACT3 | c.541G>T p.A181S | Missense Mutation (SNP) | VAF 54/208 reads (26%) | SIFT tolerated (0.41); PolyPhen benign (0.146); called by muse, mutect2, varscan2
- DAXX | c.190G>C p.E64Q | Missense Mutation (SNP) | VAF 27/236 reads (11%) | SIFT tolerated (0.4); PolyPhen benign (0.207); called by muse, mutect2, varscan2
- DCAF12L2 | c.1272G>A p.M424I | Missense Mutation (SNP) | VAF 66/283 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- DCLK1 | c.1904dup p.F636Ifs*8 | Frame Shift Ins (INS) | VAF 52/227 reads (23%) | called by mutect2, pindel, varscan2
- DDR2 | c.1447G>T p.E483* | Nonsense Mutation (SNP) | VAF 179/427 reads (42%) | called by muse, mutect2, varscan2
- DEF6 | c.193A>T p.S65C | Missense Mutation (SNP) | VAF 28/412 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2
- DERA | c.478A>G p.R160G | Missense Mutation (SNP) | VAF 86/229 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- DESI1 | c.279G>T p.E93D | Missense Mutation (SNP) | VAF 84/260 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- DGCR6L | c.459G>C p.Q153H | Missense Mutation (SNP) | VAF 20/618 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
1,496 further variants in this file (787 protein-altering or splice-affecting, 431 silent, 278 other) are not listed here.
